Somatic mutation profile of tumor specimen 0DLPZG from CCDI case PBBYKI, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Vital status: Alive; Primary diagnosis: Glioma, malignant; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 5.1 years (1,864 days).
Specimen 0DLPZG: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 9223a069-a7a3-479c-8749-c163ae86f662.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DLQ01 (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/644b9e9c-90fe-4729-a0b9-3a9c2c9418ff

The open-access MAF lists 6,246 somatic variants for this specimen: 3,940 protein-altering or splice-affecting, 1,053 silent, 1,253 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 3,149, Silent 1,053, Intron 749, 3'UTR 272, Nonsense Mutation 241, Frame Shift Del 198, Splice Site 164, 5'UTR 150, Frame Shift Ins 94, Splice Region 84, 5'Flank 38, 3'Flank 24.

Variants (750 of 6,246; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ASPA | c.697del p.R233Gfs*31 | Frame Shift Del (DEL) | VAF 243/631 reads (39%) | catalogued as rs1057516315, CM940123; ClinVar: likely pathogenic; called by mutect2, varscan2
- DCX | c.586C>T p.R196C | Missense Mutation (SNP) | VAF 266/318 reads (84%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as rs587783568, CM023363, CM087666; ClinVar: pathogenic / likely pathogenic; called by muse, varscan2
- DYSF | c.4200del p.I1401Sfs*47 | Frame Shift Del (DEL) | VAF 176/420 reads (42%) | catalogued as rs398123786, CM053841; ClinVar: pathogenic; called by mutect2, varscan2
- FBN1 | c.6970G>A p.A2324T | Missense Mutation (SNP) | VAF 269/657 reads (41%) | SIFT tolerated (0.32); PolyPhen benign (0.094); catalogued as rs148831709; ClinVar: likely pathogenic / uncertain significance; called by muse, mutect2, varscan2
- FLNB | c.1592del p.G531Dfs*42 | Frame Shift Del (DEL) | VAF 184/480 reads (38%) | catalogued as rs746105983; ClinVar: pathogenic; called by mutect2, varscan2
- KMT2A | c.4504C>T p.R1502* | Nonsense Mutation (SNP) | VAF 237/672 reads (35%) | catalogued as rs150800017; ClinVar: pathogenic; called by muse, mutect2, varscan2
- LOXHD1 | c.5002C>T p.R1668* | Nonsense Mutation (SNP) | VAF 40/543 reads (7%) | catalogued as rs961865375, COSV56060971; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2
- MSH2 | c.943-1G>T p.X315_splice | Splice Site (SNP) | VAF 138/323 reads (43%) | catalogued as rs12476364, CS056119, COSV51878555, COSV99028463; ClinVar: pathogenic; called by muse, mutect2, varscan2
- MSH6 | c.3312dup p.G1105Wfs*3 | Frame Shift Ins (INS) | VAF 108/286 reads (38%) | catalogued as rs267608092; ClinVar: not provided / pathogenic; called by mutect2, varscan2
- MYO7A | c.3G>A p.M1? | Translation Start Site (SNP) | VAF 118/332 reads (36%) | SIFT deleterious (0.01); PolyPhen benign (0.187); catalogued as rs782787126; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- MYO7A | c.397del p.H133Tfs*13 | Frame Shift Del (DEL) | VAF 148/362 reads (41%) | catalogued as rs111033187; ClinVar: likely pathogenic; called by mutect2, varscan2
- POLD1 | c.1433G>A p.S478N | Missense Mutation (SNP) | VAF 177/427 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.957); catalogued as rs397514632, CM1212503, COSV70955559; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- PTPN11 | c.1530G>T p.Q510H | Missense Mutation (SNP) | VAF 282/782 reads (36%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as CM117756, COSV61005626, COSV61006865; called by muse, mutect2, varscan2
- SH2D1A | c.192G>A p.W64* | Nonsense Mutation (SNP) | VAF 347/431 reads (81%) | catalogued as rs1556620706, CM1010332, COSV63578669, COSV63578834; ClinVar: pathogenic; called by muse, mutect2, varscan2
- TP53 | c.920-1G>T p.X307_splice | Splice Site (SNP) | VAF 173/409 reads (42%) | hotspot (GDC flag); catalogued as rs587781702, CS0910927, CS114009, COSV52664150, COSV52690279, COSV52737535; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- AACS | c.1075del p.L359Wfs*15 | Frame Shift Del (DEL) | VAF 68/526 reads (13%) | catalogued as COSV55538357; called by mutect2, varscan2
- AARS2 | c.1696G>A p.A566T | Missense Mutation (SNP) | VAF 196/428 reads (46%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.81); catalogued as rs764610166; called by muse, mutect2, varscan2
- ABCA13 | c.8364C>A p.D2788E | Missense Mutation (SNP) | VAF 338/876 reads (39%) | SIFT tolerated (0.19); PolyPhen benign (0.013); catalogued as COSV101446722; called by muse, mutect2, varscan2
- ABCA13 | c.8981C>T p.P2994L | Missense Mutation (SNP) | VAF 162/546 reads (30%) | SIFT deleterious (0.03); PolyPhen benign (0.086); catalogued as rs759857903, COSV71282609; called by muse, varscan2
- ABCA9 | c.810G>A p.W270* | Nonsense Mutation (SNP) | VAF 29/773 reads (4%) | catalogued as COSV100382492; called by muse, mutect2
- ABCB11 | c.1715C>T p.A572V | Missense Mutation (SNP) | VAF 280/732 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs748529595; called by muse, mutect2, varscan2
- ABCC1 | c.457C>A p.L153M | Missense Mutation (SNP) | VAF 26/648 reads (4%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.498); catalogued as COSV60682720; called by muse, mutect2
- ABCG2 | c.565G>A p.G189R | Missense Mutation (SNP) | VAF 64/549 reads (12%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.548); catalogued as COSV52947523; called by muse, mutect2, varscan2
- ABL2 | c.281G>T p.R94M (on ENST00000502732 / NM_007314.4; = p.R79M on NM_005158.5) | Missense Mutation (SNP) | VAF 353/852 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100772605; called by muse, mutect2, varscan2
- ACAD8 | c.494G>A p.S165N | Missense Mutation (SNP) | VAF 24/522 reads (5%) | SIFT deleterious (0.02); PolyPhen benign (0.35); catalogued as rs988461205; called by muse, mutect2
- ACKR2 | c.218G>A p.R73H | Missense Mutation (SNP) | VAF 48/611 reads (8%) | SIFT tolerated (0.51); PolyPhen benign (0.031); catalogued as rs772013246, COSV56177434; called by muse, mutect2
- ACOT11 | c.1585T>C p.C529R | Missense Mutation (SNP) | VAF 55/749 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs375908312; called by muse, mutect2
- ACOT2 | c.133C>A p.L45M | Missense Mutation (SNP) | VAF 26/508 reads (5%) | SIFT tolerated (0.22); PolyPhen benign (0.094); catalogued as COSV53151515; called by muse, mutect2
- ACSBG1 | c.265C>T p.R89W | Missense Mutation (SNP) | VAF 142/365 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.676); catalogued as rs367755677; called by muse, mutect2, varscan2
- ADAM15 | c.2152C>T p.R718C | Missense Mutation (SNP) | VAF 68/683 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs147466706; called by muse, mutect2
- ADAM17 | c.710G>T p.R237I | Missense Mutation (SNP) | VAF 98/1229 reads (8%) | SIFT deleterious (0.01); PolyPhen benign (0.134); catalogued as COSV60398652; called by muse, mutect2
- ADAM32 | c.1237T>C p.C413R | Missense Mutation (SNP) | VAF 231/633 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1208976072; called by muse, mutect2, varscan2
- ADAM33 | c.1134-3T>C | Splice Region (SNP) | VAF 17/476 reads (4%) | catalogued as rs1219057877; called by muse, mutect2
- ADAMTS20 | c.3511G>T p.G1171C | Missense Mutation (SNP) | VAF 72/704 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV67138490; called by muse, mutect2
- ADAMTSL3 | c.4882A>G p.R1628G | Missense Mutation (SNP) | VAF 236/513 reads (46%) | SIFT tolerated (0.18); PolyPhen benign (0); catalogued as COSV54436064; called by muse, mutect2, varscan2
- ADCK2 | c.1877del p.P626Rfs*38 | Frame Shift Del (DEL) | VAF 155/382 reads (41%) | catalogued as rs750981657; called by mutect2, varscan2
- ADCY5 | c.3339G>T p.E1113D | Missense Mutation (SNP) | VAF 80/834 reads (10%) | SIFT deleterious (0.01); PolyPhen benign (0.118); catalogued as COSV100568347; called by muse, mutect2
- ADGRA3 | c.3602G>A p.S1201N | Missense Mutation (SNP) | VAF 267/642 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV51567491; called by muse, mutect2, varscan2
- ADGRL4 | c.1609G>T p.G537C | Missense Mutation (SNP) | VAF 392/1025 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV100876032; called by muse, varscan2
- ADGRV1 | c.15622G>A p.A5208T | Missense Mutation (SNP) | VAF 46/926 reads (5%) | SIFT tolerated (0.05); PolyPhen benign (0); catalogued as rs1023881798; called by muse, mutect2
- ADPRM | c.742G>A p.A248T | Missense Mutation (SNP) | VAF 392/1136 reads (35%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.627); catalogued as rs199523732; called by muse, mutect2, varscan2
- AFG1L | c.1336T>A p.S446T | Missense Mutation (SNP) | VAF 68/816 reads (8%) | SIFT tolerated (0.12); PolyPhen benign (0.031); catalogued as rs772619387; called by muse, mutect2
- AFM | c.650C>A p.S217Y | Missense Mutation (SNP) | VAF 85/1051 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.916); catalogued as COSV56919193; called by muse, mutect2
- AGBL4 | c.1450C>T p.P484S | Missense Mutation (SNP) | VAF 329/804 reads (41%) | SIFT tolerated, low confidence (0.21); PolyPhen benign (0); catalogued as rs896465817; called by muse, mutect2, varscan2
- AKAP7 | c.652C>A p.P218T | Missense Mutation (SNP) | VAF 52/1177 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1398038977, COSV53833888; called by muse, mutect2
- ALPK2 | c.6443G>T p.S2148I | Missense Mutation (SNP) | VAF 56/785 reads (7%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.825); catalogued as rs750802597; called by muse, mutect2
- ALPK2 | c.1681A>G p.T561A | Missense Mutation (SNP) | VAF 15/266 reads (6%) | SIFT deleterious (0.03); PolyPhen benign (0.007); catalogued as COSV64495025; called by muse, mutect2
- AMBRA1 | c.3746C>T p.P1249L (on ENST00000458649 / NM_001367468.1; = p.P1159L on NM_017749.3 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 100/218 reads (46%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.015); catalogued as rs1270110447; called by muse, mutect2, varscan2
- AMER3 | c.2132C>T p.A711V | Missense Mutation (SNP) | VAF 67/624 reads (11%) | SIFT tolerated (0.24); PolyPhen benign (0.009); catalogued as rs1412325586; called by muse, mutect2, varscan2
- ANK2 | c.7124C>T p.T2375I | Missense Mutation (SNP) | VAF 342/856 reads (40%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.003); catalogued as rs1327072432; called by muse, mutect2, varscan2
- ANKIB1 | c.1486C>T p.L496F | Missense Mutation (SNP) | VAF 342/963 reads (36%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.715); catalogued as rs748799440, COSV99728071; called by muse, mutect2, varscan2
- ANKRD18B | c.871del p.R291Efs*11 | Frame Shift Del (DEL) | VAF 349/905 reads (39%) | catalogued as rs1394861556; called by mutect2, varscan2
- ANKRD26 | c.5071G>A p.D1691N | Missense Mutation (SNP) | VAF 72/1128 reads (6%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.534); catalogued as COSV101063470, COSV65776956; called by muse, mutect2
- ANKRD31 | c.4263dup p.Q1422Tfs*12 | Frame Shift Ins (INS) | VAF 436/1123 reads (39%) | catalogued as rs530301594; called by mutect2, varscan2
- ANKRD31 | c.1533del p.G512Vfs*20 | Frame Shift Del (DEL) | VAF 299/760 reads (39%) | catalogued as rs1279723268; called by mutect2, varscan2
- ANKRD33 | c.701C>A p.S234Y (on ENST00000340970 / NM_001304459.2; = p.L426M on NM_182608.4) | Missense Mutation (SNP) | VAF 40/312 reads (13%) | SIFT deleterious (0.03); PolyPhen benign (0.06); catalogued as COSV100001285; called by muse, varscan2
- ANKRD52 | c.1054G>A p.E352K | Missense Mutation (SNP) | VAF 166/449 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.832); catalogued as rs774975259; called by muse, mutect2, varscan2
- ANLN | c.82A>G p.T28A | Missense Mutation (SNP) | VAF 335/867 reads (39%) | SIFT tolerated (0.07); PolyPhen benign (0.092); catalogued as rs1402764112; called by muse, mutect2, varscan2
- ANO3 | c.738G>A p.R246= | Splice Region (SNP) | VAF 195/475 reads (41%) | catalogued as COSV56809859; called by muse, mutect2, varscan2
- ANO9 | c.2080C>A p.Q694K | Missense Mutation (SNP) | VAF 211/578 reads (37%) | SIFT tolerated (0.1); PolyPhen benign (0.015); catalogued as rs777159075; called by muse, mutect2, varscan2
- APOB | c.6259A>C p.T2087P | Missense Mutation (SNP) | VAF 44/1028 reads (4%) | SIFT tolerated (0.11); PolyPhen benign (0.124); catalogued as rs1441625656; called by muse, mutect2
- AQP5 | c.341G>A p.R114Q | Missense Mutation (SNP) | VAF 69/563 reads (12%) | SIFT tolerated (0.05); PolyPhen benign (0.223); catalogued as rs1234813760; called by muse, mutect2, varscan2
- ARAP2 | c.1589C>A p.S530Y | Missense Mutation (SNP) | VAF 235/686 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as COSV58293700; called by muse, mutect2, varscan2
- ARHGAP42 | c.2141C>T p.S714F | Missense Mutation (SNP) | VAF 230/680 reads (34%) | SIFT deleterious (0); PolyPhen benign (0.006); catalogued as rs529466797; called by muse, mutect2, varscan2
- ARHGAP44 | c.256G>A p.G86R | Missense Mutation (SNP) | VAF 358/940 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV52394219; called by muse, mutect2, varscan2
- ARHGEF1 | c.1623G>T p.Q541H | Missense Mutation (SNP) | VAF 86/263 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as rs55795616; called by muse, mutect2, varscan2
- ARHGEF10L | c.1928-1G>T p.X643_splice | Splice Site (SNP) | VAF 149/294 reads (51%) | catalogued as COSV51436507; called by muse, mutect2, varscan2
- ARHGEF11 | c.3364G>T p.G1122C | Missense Mutation (SNP) | VAF 210/585 reads (36%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0); catalogued as rs1189374222; called by muse, mutect2, varscan2
- ARHGEF25 | c.394G>T p.G132* | Nonsense Mutation (SNP) | VAF 58/558 reads (10%) | catalogued as rs754473725; called by muse, mutect2, varscan2
- ARID1B | c.3854A>G p.Q1285R | Missense Mutation (SNP) | VAF 76/929 reads (8%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.062); catalogued as COSV51669428; called by muse, mutect2
- ARID1B | c.6529C>T p.P2177S | Missense Mutation (SNP) | VAF 200/543 reads (37%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.824); catalogued as rs761917637; called by muse, mutect2, varscan2
- ARID4A | c.1963G>A p.E655K | Missense Mutation (SNP) | VAF 283/792 reads (36%) | SIFT deleterious (0.02); PolyPhen benign (0.042); catalogued as rs566037632, COSV62162589; called by muse, mutect2, varscan2
- ARID4B | c.3334G>T p.A1112S | Missense Mutation (SNP) | VAF 210/557 reads (38%) | SIFT tolerated (0.2); PolyPhen benign (0.161); catalogued as COSV51607979; called by muse, mutect2, varscan2
- ARL13B | c.1154C>T p.T385I (on ENST00000394222 / NM_001174150.2; = p.T278I on NM_144996.4) | Missense Mutation (SNP) | VAF 349/990 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.957); catalogued as rs774627143; called by muse, mutect2, varscan2
- ARMC6 | c.732G>T p.W244C (on ENST00000392336; = p.W219C on NM_033415.4) | Missense Mutation (SNP) | VAF 20/467 reads (4%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.814); catalogued as COSV99523132; called by muse, mutect2
- ARSA | c.1441C>T p.R481W | Missense Mutation (SNP) | VAF 153/356 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.637); catalogued as rs747443475; called by muse, mutect2, varscan2
- ASAH2 | c.148del p.S50Qfs*40 | Frame Shift Del (DEL) | VAF 194/475 reads (41%) | catalogued as rs772181094; called by mutect2, varscan2
- ASL | c.572G>A p.R191Q | Missense Mutation (SNP) | VAF 225/520 reads (43%) | SIFT tolerated (0.39); PolyPhen benign (0.031); catalogued as rs183157856; called by muse, varscan2
- ASPA | c.694C>T p.P232S | Missense Mutation (SNP) | VAF 248/632 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53981164; called by mutect2, varscan2
- ASXL2 | c.2536C>T p.P846S | Missense Mutation (SNP) | VAF 286/821 reads (35%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.265); catalogued as rs760967903, COSV99712413; called by muse, mutect2, varscan2
- ATAD2 | c.4030dup p.S1344Kfs*28 | Frame Shift Ins (INS) | VAF 158/430 reads (37%) | catalogued as rs775812316; called by mutect2, varscan2
- ATAD5 | c.1841C>A p.S614Y | Missense Mutation (SNP) | VAF 378/854 reads (44%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.578); catalogued as COSV100429938; called by muse, mutect2, varscan2
- ATF7 | c.736C>T p.P246S (on ENST00000548446 / NM_001366555.2; = p.P235S on NM_006856.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 95/855 reads (11%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.987); catalogued as rs377621370; called by muse, mutect2, varscan2
- ATG4D | c.907C>A p.L303M | Missense Mutation (SNP) | VAF 33/374 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as COSV100470314; called by muse, mutect2
- ATIC | c.1327G>T p.G443C | Missense Mutation (SNP) | VAF 170/412 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52695729; called by muse, varscan2
- ATM | c.7352C>T p.A2451V | Missense Mutation (SNP) | VAF 277/681 reads (41%) | SIFT deleterious (0.02); PolyPhen benign (0.258); catalogued as COSV104377429; called by muse, mutect2, varscan2
- ATN1 | c.2818C>T p.R940* | Nonsense Mutation (SNP) | VAF 206/549 reads (38%) | catalogued as COSV63111674; called by muse, mutect2, varscan2
- ATP2A3 | c.1673C>T p.T558M | Missense Mutation (SNP) | VAF 136/325 reads (42%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.61); catalogued as rs147797776; called by muse, mutect2, varscan2
- ATP2B2 | c.2588G>T p.S863I (on ENST00000352432; = p.S829I on NM_001683.5) | Missense Mutation (SNP) | VAF 281/731 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV59506974; called by muse, mutect2, varscan2
- ATP4A | c.760G>A p.A254T | Missense Mutation (SNP) | VAF 130/325 reads (40%) | SIFT tolerated (0.06); PolyPhen benign (0.209); catalogued as rs750384600, COSV99383131; called by muse, varscan2
- ATP6V1H | c.859G>A p.A287T | Missense Mutation (SNP) | VAF 37/776 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as rs1442295869; called by muse, mutect2
- ATRX | c.6892C>T p.P2298S | Missense Mutation (SNP) | VAF 73/450 reads (16%) | SIFT tolerated (0.14); PolyPhen benign (0.031); catalogued as COSV64880064, COSV64880569; called by muse, mutect2, varscan2
- ATRX | c.3809G>T p.R1270I | Missense Mutation (SNP) | VAF 316/373 reads (85%) | SIFT deleterious (0); PolyPhen possibly damaging (0.896); catalogued as COSV100970067; called by muse, mutect2, varscan2
- AUP1 | c.189-1G>T p.X63_splice | Splice Site (SNP) | VAF 123/310 reads (40%) | catalogued as COSV99239378; called by muse, mutect2, varscan2
- AXDND1 | c.1685G>A p.R562Q | Missense Mutation (SNP) | VAF 306/784 reads (39%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as rs368301278; called by muse, mutect2, varscan2
- B3GNT4 | c.195C>A p.F65L | Missense Mutation (SNP) | VAF 126/309 reads (41%) | SIFT tolerated (0.33); PolyPhen benign (0.039); catalogued as COSV99928223; called by muse, mutect2, varscan2
- BAG5 | c.742G>T p.D248Y | Missense Mutation (SNP) | VAF 238/565 reads (42%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.934); catalogued as rs1337425535; called by muse, mutect2, varscan2
- BCL11A | c.2327G>A p.S776N (on ENST00000335712 / NM_001365609.1; = p.S810N on NM_022893.4) | Missense Mutation (SNP) | VAF 222/588 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.451); catalogued as COSV59638491; called by muse, mutect2, varscan2
- BFAR | c.228dup p.W77Mfs*16 | Frame Shift Ins (INS) | VAF 174/587 reads (30%) | catalogued as rs989078533; called by mutect2, varscan2
- BLK | c.25C>A p.P9T | Missense Mutation (SNP) | VAF 212/610 reads (35%) | SIFT tolerated (0.35); PolyPhen benign (0.006); catalogued as rs748344961, COSV99376878; called by muse, mutect2, varscan2
- BMPR2 | c.1168G>T p.G390* | Nonsense Mutation (SNP) | VAF 41/922 reads (4%) | catalogued as COSV65808887, COSV65810518; called by muse, mutect2
- BMT2 | c.879G>T p.W293C | Missense Mutation (SNP) | VAF 354/867 reads (41%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.864); catalogued as COSV51781411; called by muse, mutect2, varscan2
- BNC1 | c.1211G>A p.R404H | Missense Mutation (SNP) | VAF 217/611 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV61756516; called by muse, mutect2, varscan2
- BOP1 | c.934G>A p.E312K | Missense Mutation (SNP) | VAF 220/563 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.93); catalogued as rs1008946352; called by muse, mutect2, varscan2
- BPIFB3 | c.1149+1G>A p.X383_splice | Splice Site (SNP) | VAF 123/355 reads (35%) | catalogued as rs147342520; called by muse, mutect2, varscan2
- BRCA2 | c.5084A>G p.E1695G | Missense Mutation (SNP) | VAF 472/1146 reads (41%) | SIFT deleterious (0.03); PolyPhen benign (0.026); catalogued as rs397507347; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- BRPF1 | c.290G>A p.R97H | Missense Mutation (SNP) | VAF 255/567 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.915); catalogued as rs971945646, COSV57408120; called by muse, mutect2, varscan2
- BRSK2 | c.1063dup p.R355Pfs*48 | Frame Shift Ins (INS) | VAF 135/344 reads (39%) | catalogued as rs779380593; called by mutect2, varscan2
- C13orf42 | c.130del p.D44Tfs*10 | Frame Shift Del (DEL) | VAF 72/428 reads (17%) | catalogued as rs1420240072; called by mutect2, varscan2
- C15orf62 | c.394C>T p.P132S | Missense Mutation (SNP) | VAF 121/294 reads (41%) | SIFT tolerated (0.65); PolyPhen benign (0.003); catalogued as rs777934673; called by muse, mutect2, varscan2
- C16orf72 | c.823A>T p.I275F | Missense Mutation (SNP) | VAF 35/346 reads (10%) | SIFT tolerated (0.12); PolyPhen benign (0.408); catalogued as COSV59915593; called by muse, mutect2, varscan2
- C16orf96 | c.3211C>A p.L1071M | Missense Mutation (SNP) | VAF 21/531 reads (4%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.465); catalogued as COSV71471535; called by muse, mutect2
- C1QTNF2 | c.485C>T p.P162L (on ENST00000393975; = p.P117L on NM_031908.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 45/570 reads (8%) | SIFT tolerated (0.83); PolyPhen benign (0.442); catalogued as COSV67432961; called by muse, mutect2
- C2orf16 | c.4915C>T p.R1639C | Missense Mutation (SNP) | VAF 304/708 reads (43%) | SIFT tolerated (0.1); PolyPhen benign (0.005); catalogued as rs1426537450, COSV62675332; called by muse, mutect2, varscan2
- C3orf20 | c.1663T>A p.F555I | Missense Mutation (SNP) | VAF 122/1321 reads (9%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.833); catalogued as COSV53784339; called by muse, mutect2
- C6orf118 | c.1262G>T p.G421V | Missense Mutation (SNP) | VAF 226/647 reads (35%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.815); catalogued as COSV57818482; called by muse, mutect2, varscan2
- C8orf48 | c.880C>T p.H294Y | Missense Mutation (SNP) | VAF 378/948 reads (40%) | SIFT tolerated, low confidence (0.21); PolyPhen possibly damaging (0.644); catalogued as rs542176418; called by muse, mutect2, varscan2
- CA5A | c.676G>A p.D226N | Missense Mutation (SNP) | VAF 34/614 reads (6%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.939); catalogued as rs1280675833; ClinVar: uncertain significance; called by muse, mutect2
- CACNB2 | c.1124C>T p.A375V (on ENST00000324631 / NM_201596.3; = p.A320V on NM_000724.4) | Missense Mutation (SNP) | VAF 263/720 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); catalogued as rs578106427, COSV56622691; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CALHM2 | c.783G>T p.E261D | Missense Mutation (SNP) | VAF 190/464 reads (41%) | SIFT deleterious (0.04); PolyPhen benign (0.06); catalogued as rs373034255; called by muse, mutect2, varscan2
- CAMSAP3 | c.1361G>T p.G454V | Missense Mutation (SNP) | VAF 8/98 reads (8%) | SIFT deleterious (0); PolyPhen benign (0.039); catalogued as COSV50332024; called by muse, mutect2, varscan2
- CASR | c.2986G>A p.E996K (on ENST00000490131; = p.E1073K on NM_000388.4) | Missense Mutation (SNP) | VAF 36/996 reads (4%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.969); catalogued as rs1239677065; called by muse, mutect2
- CASS4 | c.811G>A p.A271T | Missense Mutation (SNP) | VAF 74/625 reads (12%) | SIFT tolerated (0.57); PolyPhen benign (0); catalogued as rs771671673, COSV64386420, COSV64386735, COSV64386803; called by muse, varscan2
- CATSPER1 | c.2075G>A p.R692Q | Missense Mutation (SNP) | VAF 34/433 reads (8%) | SIFT tolerated (0.42); PolyPhen benign (0.01); catalogued as rs369647718; called by muse, mutect2
- CATSPERD | c.302C>T p.A101V | Missense Mutation (SNP) | VAF 48/466 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.941); catalogued as rs1355730634; called by muse, mutect2
- CCDC102A | c.1558G>A p.G520R | Missense Mutation (SNP) | VAF 184/507 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs568309798, COSV99265279; called by muse, mutect2, varscan2
- CCDC106 | c.403G>A p.A135T | Missense Mutation (SNP) | VAF 26/460 reads (6%) | SIFT tolerated (0.39); PolyPhen benign (0.107); catalogued as COSV100454376; called by muse, mutect2
- CCDC134 | c.242G>A p.R81Q | Missense Mutation (SNP) | VAF 28/478 reads (6%) | SIFT deleterious (0.03); PolyPhen benign (0.087); catalogued as rs975926289; called by muse, mutect2
- CCDC152 | c.671dup p.N224Kfs*9 | Frame Shift Ins (INS) | VAF 79/560 reads (14%) | catalogued as rs920626028; called by mutect2, varscan2
- CCDC162P | n.2888G>T | Splice Region (SNP) | VAF 156/412 reads (38%) | catalogued as rs1030088340; called by muse, mutect2, varscan2
- CCDC178 | c.211G>A p.V71M | Missense Mutation (SNP) | VAF 36/400 reads (9%) | SIFT tolerated (0.15); PolyPhen benign (0.4); catalogued as rs138740715; called by muse, mutect2
- CCDC181 | c.1265del p.K422Sfs*6 (on ENST00000367806 / NM_001300969.1; = p.K421Sfs*6 on NM_021179.2) | Frame Shift Del (DEL) | VAF 438/1085 reads (40%) | catalogued as rs759258977; called by mutect2, varscan2
- CCDC191 | c.2357C>T p.T786M | Missense Mutation (SNP) | VAF 335/764 reads (44%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.736); catalogued as rs762932133, COSV55670345; called by muse, varscan2
- CCDC85A | c.1382C>A p.S461Y | Missense Mutation (SNP) | VAF 471/1170 reads (40%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.084); catalogued as COSV68151792, COSV68156554; called by muse, mutect2, varscan2
- CCKBR | c.1220G>A p.R407H | Missense Mutation (SNP) | VAF 118/274 reads (43%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.891); catalogued as rs1197838113; called by muse, varscan2
- CCL1 | c.44G>T p.G15V | Missense Mutation (SNP) | VAF 260/690 reads (38%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.797); catalogued as COSV56774408; called by muse, mutect2, varscan2
- CCN6 | c.667T>C p.C223R | Missense Mutation (SNP) | VAF 394/882 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs782813346, CM118812; called by muse, mutect2, varscan2
- CCNDBP1 | c.691T>A p.L231M | Missense Mutation (SNP) | VAF 56/656 reads (9%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.526); catalogued as COSV55746827; called by muse, mutect2
- CCNF | c.1517G>T p.R506M | Missense Mutation (SNP) | VAF 35/368 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs759632058, COSV53540740; called by muse, mutect2
- CCP110 | c.1869G>T p.K623N | Missense Mutation (SNP) | VAF 261/640 reads (41%) | SIFT tolerated (0.41); PolyPhen benign (0.117); catalogued as COSV101195286; called by muse, mutect2, varscan2
- CCR7 | c.672G>T p.Q224H | Missense Mutation (SNP) | VAF 168/388 reads (43%) | SIFT tolerated (0.29); PolyPhen possibly damaging (0.852); catalogued as COSV55848934; called by muse, mutect2, varscan2
- CD177 | c.1282C>A p.L428M | Missense Mutation (SNP) | VAF 92/285 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.976); catalogued as rs1468198577; called by muse, mutect2, varscan2
- CD27 | c.428C>T p.T143I | Missense Mutation (SNP) | VAF 228/607 reads (38%) | SIFT tolerated (0.08); PolyPhen benign (0.059); catalogued as rs1285656336; called by muse, mutect2, varscan2
- CDC14A | c.268C>T p.R90W | Missense Mutation (SNP) | VAF 376/1003 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.585); catalogued as rs772919579, COSV60556097; called by muse, mutect2, varscan2
- CDC14A | c.1185G>T p.Q395H | Missense Mutation (SNP) | VAF 373/908 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100325025; called by muse, mutect2, varscan2
- CDCA4 | c.415A>G p.R139G | Missense Mutation (SNP) | VAF 106/243 reads (44%) | SIFT tolerated (0.35); PolyPhen benign (0.009); catalogued as rs372559200; called by muse, mutect2, varscan2
- CDH10 | c.263C>A p.S88* | Nonsense Mutation (SNP) | VAF 38/1238 reads (3%) | catalogued as COSV100051624; called by muse, mutect2
- CDH18 | c.1048G>T p.A350S | Missense Mutation (SNP) | VAF 324/814 reads (40%) | SIFT tolerated (1); PolyPhen benign (0.079); catalogued as COSV56900877, COSV56970541; called by muse, varscan2
- CDH23 | c.8212C>T p.P2738S | Missense Mutation (SNP) | VAF 172/488 reads (35%) | SIFT tolerated (0.14); PolyPhen benign (0.408); catalogued as rs1259106647; called by muse, mutect2, varscan2
- CDH24 | c.2350G>A p.G784S | Missense Mutation (SNP) | VAF 187/490 reads (38%) | SIFT tolerated (0.74); PolyPhen benign (0.007); catalogued as rs1046986201; called by muse, mutect2, varscan2
- CDH4 | c.2332G>A p.D778N | Missense Mutation (SNP) | VAF 206/577 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV64642685; called by muse, mutect2, varscan2
- CDH7 | c.2341G>A p.E781K | Missense Mutation (SNP) | VAF 235/568 reads (41%) | SIFT tolerated (0.11); PolyPhen benign (0.007); catalogued as rs374255064; called by muse, mutect2, varscan2
- CDK10 | c.594G>T p.K198N (on ENST00000353379 / NM_052988.5; = p.K127N on NM_052987.4) | Missense Mutation (SNP) | VAF 176/475 reads (37%) | SIFT tolerated (0.52); PolyPhen benign (0.007); catalogued as COSV57046314; called by muse, mutect2, varscan2
- CDK11A | c.235G>T p.E79* | Nonsense Mutation (SNP) | VAF 348/914 reads (38%) | catalogued as rs749100082; called by muse, mutect2
- CDS2 | c.1249C>T p.R417W | Missense Mutation (SNP) | VAF 71/1086 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.676); catalogued as rs758565107, COSV100986050; called by muse, mutect2
- CELF2 | c.460C>T p.P154S (on ENST00000416382 / NM_001025077.3; = p.P161S on NM_006561.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 58/902 reads (6%) | SIFT tolerated (0.36); PolyPhen benign (0.015); catalogued as rs766025296; called by muse, mutect2
- CELF4 | c.1369A>G p.T457A | Missense Mutation (SNP) | VAF 216/586 reads (37%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV58458754; called by muse, varscan2
- CELSR3 | c.2624G>A p.S875N | Missense Mutation (SNP) | VAF 48/232 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); catalogued as rs1205128717; called by muse, varscan2
- CEMIP2 | c.509G>T p.R170I | Missense Mutation (SNP) | VAF 50/1116 reads (4%) | SIFT deleterious (0.02); PolyPhen benign (0.109); catalogued as COSV100987504; called by muse, mutect2
- CEP170B | c.3413C>A p.T1138N (on ENST00000453495; = p.T1067N on NM_015005.3) | Missense Mutation (SNP) | VAF 12/202 reads (6%) | SIFT tolerated (1); PolyPhen benign (0.073); catalogued as rs1410382491; called by muse, mutect2
- CEP41 | c.1028G>A p.R343Q | Missense Mutation (SNP) | VAF 135/878 reads (15%) | SIFT deleterious (0.03); PolyPhen benign (0.441); catalogued as rs782089459, COSV56219713; called by muse, mutect2, varscan2
- CERS5 | c.389G>T p.R130M | Missense Mutation (SNP) | VAF 98/1160 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV58188712; called by muse, mutect2
- CFAP221 | c.1247A>T p.D416V | Missense Mutation (SNP) | VAF 117/868 reads (13%) | SIFT deleterious (0.01); PolyPhen benign (0.076); catalogued as rs1208612195; called by muse, mutect2, varscan2
- CFAP44 | c.3676G>A p.A1226T | Missense Mutation (SNP) | VAF 82/1264 reads (6%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.641); catalogued as COSV57663325; called by muse, mutect2
- CFAP44 | c.3070C>T p.R1024* | Nonsense Mutation (SNP) | VAF 124/365 reads (34%) | catalogued as rs921491856, COSV67249394; called by muse, mutect2, varscan2
- CFAP57 | c.2120G>A p.R707H | Missense Mutation (SNP) | VAF 42/658 reads (6%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.757); catalogued as rs1023728196; called by muse, mutect2
- CFAP69 | c.1873T>A p.F625I | Missense Mutation (SNP) | VAF 51/871 reads (6%) | SIFT tolerated (0.34); PolyPhen benign (0.194); catalogued as rs762305642, COSV60189891; called by muse, mutect2
- CFAP91 | c.1484C>A p.A495D | Missense Mutation (SNP) | VAF 152/458 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1487866520; called by muse, mutect2, varscan2
- CHAD | c.322del p.H108Ifs*15 | Frame Shift Del (DEL) | VAF 156/390 reads (40%) | catalogued as COSV99366182; called by mutect2, varscan2
- CHCHD5 | c.28C>T p.R10C | Missense Mutation (SNP) | VAF 108/1065 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.897); catalogued as rs199607921; called by muse, mutect2
- CHD5 | c.4967T>C p.I1656T | Missense Mutation (SNP) | VAF 151/394 reads (38%) | SIFT tolerated, low confidence (0.58); PolyPhen benign (0); catalogued as rs1174697815; called by muse, mutect2, varscan2
- CHD6 | c.434C>T p.P145L | Missense Mutation (SNP) | VAF 287/661 reads (43%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.078); catalogued as rs556078000; called by muse, mutect2, varscan2
- CHD7 | c.4185G>T p.Q1395H | Missense Mutation (SNP) | VAF 50/1114 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as CM074740; called by muse, mutect2
- CHD8 | c.1508G>T p.R503M (on ENST00000646647 / NM_001170629.2; = p.R224M on NM_020920.4) | Missense Mutation (SNP) | VAF 284/760 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); catalogued as COSV67869514; called by mutect2, varscan2
- CHD9 | c.1581T>A p.N527K | Missense Mutation (SNP) | VAF 83/1238 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV68299950; called by muse, mutect2
- CHEK2 | c.1657del p.Q553Rfs*3 (on ENST00000382580 / NM_001005735.2; = p.Q510Rfs*3 on NM_007194.4) | Frame Shift Del (DEL) | VAF 322/828 reads (39%) | catalogued as CM110736; called by mutect2, varscan2
- CHPT1 | c.653C>A p.P218H | Missense Mutation (SNP) | VAF 173/580 reads (30%) | SIFT deleterious (0.01); PolyPhen benign (0.274); catalogued as COSV99977905; called by muse, mutect2, varscan2
- CHRD | c.1024G>T p.G342W | Missense Mutation (SNP) | VAF 281/656 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99200220; called by muse, mutect2, varscan2
- CHRM5 | c.644G>A p.R215Q | Missense Mutation (SNP) | VAF 63/511 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.916); catalogued as rs774588600, COSV67246946; called by muse, mutect2, varscan2
- CHST10 | c.641G>T p.R214M | Missense Mutation (SNP) | VAF 28/766 reads (4%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.634); catalogued as COSV99958836; called by muse, mutect2
- CIAO2B | c.61C>A p.Q21K | Missense Mutation (SNP) | VAF 60/454 reads (13%) | SIFT tolerated (0.48); PolyPhen benign (0); catalogued as COSV57695912; called by muse, mutect2, varscan2
- CLCN6 | c.2298C>T p.S766= | Splice Region (SNP) | VAF 240/553 reads (43%) | catalogued as rs531440933, COSV100412187; ClinVar: likely benign; called by muse, varscan2
- CLCN7 | c.1346C>T p.P449L | Missense Mutation (SNP) | VAF 145/381 reads (38%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.977); catalogued as rs750628872; called by muse, mutect2, varscan2
- CLIC3 | c.256C>A p.L86M | Missense Mutation (SNP) | VAF 183/493 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs778833124; called by muse, mutect2, varscan2
- CLK4 | c.349C>T p.R117C | Missense Mutation (SNP) | VAF 319/816 reads (39%) | SIFT tolerated (0.06); PolyPhen benign (0.27); catalogued as rs752872069, COSV60319307; called by muse, mutect2, varscan2
- CLSPN | c.3434A>G p.D1145G | Missense Mutation (SNP) | VAF 291/783 reads (37%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.987); catalogued as rs933894322, COSV52054702; called by muse, mutect2, varscan2
- CMYA5 | c.10454G>T p.R3485M | Missense Mutation (SNP) | VAF 441/1158 reads (38%) | SIFT tolerated (0.27); PolyPhen benign (0.001); catalogued as COSV101483947; called by muse, mutect2, varscan2
- CNDP2 | c.668G>T p.S223I | Missense Mutation (SNP) | VAF 117/806 reads (15%) | SIFT deleterious (0.05); PolyPhen benign (0.254); catalogued as COSV60840807; called by muse, mutect2, varscan2
- CNGB1 | c.145G>T p.E49* | Nonsense Mutation (SNP) | VAF 200/523 reads (38%) | catalogued as COSV99202661; called by muse, mutect2, varscan2
- CNKSR1 | c.864G>T p.E288D (on ENST00000374253 / NM_001297647.2; = p.E281D on NM_006314.3) | Missense Mutation (SNP) | VAF 62/175 reads (35%) | SIFT tolerated (0.23); PolyPhen benign (0.093); catalogued as COSV64162934; called by mutect2, varscan2
- CNOT1 | c.2706del p.Q904Sfs*9 | Frame Shift Del (DEL) | VAF 330/868 reads (38%) | catalogued as rs1397135931, COSV55313852; called by mutect2, varscan2
- CNOT11 | c.605G>A p.R202H | Missense Mutation (SNP) | VAF 390/1037 reads (38%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.991); catalogued as rs773000440, COSV99179383; called by muse, mutect2, varscan2
- CNOT3 | c.1591G>A p.A531T | Missense Mutation (SNP) | VAF 170/437 reads (39%) | SIFT tolerated (0.4); PolyPhen benign (0); catalogued as rs587710876, COSV104378790; called by muse, mutect2, varscan2
- CNTN4 | c.1334G>T p.R445M | Missense Mutation (SNP) | VAF 56/889 reads (6%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.485); catalogued as COSV61880301; called by muse, mutect2
- COBL | c.490A>G p.T164A | Missense Mutation (SNP) | VAF 248/605 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.859); catalogued as rs1468924357; called by muse, mutect2, varscan2
- COL16A1 | c.2426G>T p.G809V | Missense Mutation (SNP) | VAF 58/733 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54714065; called by muse, mutect2
- COL16A1 | c.1676G>A p.C559Y | Missense Mutation (SNP) | VAF 178/483 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV99594935; called by muse, mutect2, varscan2
- COL1A1 | c.1667del p.P556Lfs*24 | Frame Shift Del (DEL) | VAF 158/394 reads (40%) | catalogued as rs1351742344; called by mutect2, varscan2
- COL1A2 | c.2527G>A p.A843T | Missense Mutation (SNP) | VAF 242/636 reads (38%) | SIFT tolerated (0.08); PolyPhen benign (0); catalogued as rs112697991; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- COL22A1 | c.85C>T p.R29W | Missense Mutation (SNP) | VAF 229/833 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as rs372496490; called by muse, mutect2, varscan2
- COL24A1 | c.2410G>T p.G804* | Nonsense Mutation (SNP) | VAF 208/590 reads (35%) | catalogued as COSV100993589, COSV65305085; called by muse, mutect2, varscan2
- COL27A1 | c.3194G>A p.R1065Q | Missense Mutation (SNP) | VAF 280/686 reads (41%) | SIFT tolerated (0.05); PolyPhen benign (0.001); catalogued as rs778824714, COSV100620732, COSV100620741; called by muse, mutect2, varscan2
- COL6A6 | c.5576C>T p.P1859L | Missense Mutation (SNP) | VAF 309/800 reads (39%) | SIFT tolerated (0.11); PolyPhen benign (0.183); catalogued as rs1462162670; called by muse, mutect2, varscan2
- COL9A3 | c.102dup p.G35Rfs*15 | Frame Shift Ins (INS) | VAF 76/220 reads (35%) | catalogued as rs766668875; called by mutect2, varscan2
- COLQ | c.797del p.P266Qfs*10 | Frame Shift Del (DEL) | VAF 168/405 reads (41%) | catalogued as rs1339873594; called by mutect2, varscan2
- COQ10B | c.476A>G p.N159S | Missense Mutation (SNP) | VAF 88/951 reads (9%) | SIFT tolerated (0.15); PolyPhen benign (0.039); catalogued as rs1357114564; called by muse, mutect2
- CPA5 | c.172del p.D58Ifs*5 | Frame Shift Del (DEL) | VAF 228/584 reads (39%) | catalogued as COSV62568956; called by mutect2, varscan2
- CPB1 | c.656A>G p.N219S | Missense Mutation (SNP) | VAF 28/836 reads (3%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.894); catalogued as rs1342582030, COSV51573177; called by muse, mutect2
- CPOX | c.893G>T p.R298I | Missense Mutation (SNP) | VAF 108/1227 reads (9%) | SIFT deleterious (0.02); PolyPhen benign (0.103); catalogued as rs1038446540; called by muse, mutect2
- CPSF1 | c.2912C>T p.P971L | Missense Mutation (SNP) | VAF 177/395 reads (45%) | SIFT tolerated (0.16); PolyPhen benign (0.158); catalogued as rs571420829; called by muse, mutect2, varscan2
- CPT2 | c.1393G>A p.A465T | Missense Mutation (SNP) | VAF 226/548 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.914); catalogued as rs1368254719, COSV53759774; called by muse, mutect2, varscan2
- CRACD | c.2854G>T p.A952S | Missense Mutation (SNP) | VAF 70/395 reads (18%) | SIFT tolerated (0.08); PolyPhen benign (0.068); catalogued as COSV51731668; called by muse, mutect2, varscan2
- CRAT | c.829C>T p.R277C | Missense Mutation (SNP) | VAF 183/459 reads (40%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.647); catalogued as rs377014991; called by muse, mutect2, varscan2
- CREB3 | c.898T>A p.C300S | Missense Mutation (SNP) | VAF 37/524 reads (7%) | SIFT tolerated (0.25); PolyPhen benign (0); catalogued as COSV59207985; called by muse, mutect2
- CREM | c.106C>A p.P36T | Missense Mutation (SNP) | VAF 363/934 reads (39%) | SIFT tolerated (0.51); PolyPhen benign (0.146); catalogued as COSV61319157; called by muse, mutect2, varscan2
- CRMP1 | c.712C>T p.R238W | Missense Mutation (SNP) | VAF 29/442 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61478659; called by muse, mutect2
- CRNKL1 | c.1114G>A p.V372M | Missense Mutation (SNP) | VAF 70/730 reads (10%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.806); catalogued as rs780216616; called by muse, mutect2
- CRY1 | c.1387G>A p.G463R | Missense Mutation (SNP) | VAF 36/1013 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); catalogued as COSV50481727; called by muse, mutect2
- CSDE1 | c.883A>G p.K295E (on ENST00000358528 / NM_001007553.3; = p.K264E on NM_007158.6) | Missense Mutation (SNP) | VAF 280/746 reads (38%) | SIFT tolerated (0.42); PolyPhen probably damaging (0.956); catalogued as rs1454492029; called by muse, mutect2, varscan2
- CSMD1 | c.8572A>G p.I2858V (on ENST00000520002; = p.I2857V on NM_033225.6) | Missense Mutation (SNP) | VAF 161/381 reads (42%) | SIFT tolerated (1); PolyPhen benign (0.321); catalogued as rs1438994281; called by muse, mutect2, varscan2
- CSTF2T | c.980G>A p.R327Q | Missense Mutation (SNP) | VAF 26/553 reads (5%) | SIFT tolerated, low confidence (0.11); PolyPhen probably damaging (0.99); catalogued as COSV58656003; called by muse, mutect2
- CTCFL | c.653C>T p.T218I | Missense Mutation (SNP) | VAF 418/1031 reads (41%) | SIFT deleterious (0.04); PolyPhen benign (0.169); catalogued as rs773775695; called by muse, mutect2, varscan2
- CTNNA1 | c.1223C>T p.A408V | Missense Mutation (SNP) | VAF 32/1073 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57079179; called by muse, mutect2
- CTNND1 | c.1030C>T p.R344* | Nonsense Mutation (SNP) | VAF 80/1285 reads (6%) | catalogued as COSV62381991; called by muse, mutect2
- CTSF | c.1116G>T p.K372N | Missense Mutation (SNP) | VAF 48/756 reads (6%) | SIFT tolerated (0.06); PolyPhen benign (0.127); catalogued as rs1055863767; called by muse, mutect2
- CUEDC1 | c.987G>T p.K329N | Missense Mutation (SNP) | VAF 51/1180 reads (4%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.826); catalogued as rs1332185253; called by muse, mutect2
- CUL1 | c.1770G>T p.L590F | Missense Mutation (SNP) | VAF 79/598 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); catalogued as COSV100296812; called by muse, mutect2, varscan2
- CXCR2 | c.324G>T p.K108N | Missense Mutation (SNP) | VAF 107/914 reads (12%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.908); catalogued as COSV100578943; called by muse, mutect2, varscan2
- CXCR4 | c.1021T>C p.S341P | Missense Mutation (SNP) | VAF 169/437 reads (39%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.991); catalogued as CD0911366; called by muse, mutect2, varscan2
- CYB5R1 | c.353T>C p.L118P | Missense Mutation (SNP) | VAF 32/922 reads (3%) | SIFT deleterious (0); PolyPhen possibly damaging (0.489); catalogued as rs1425952700; called by muse, mutect2
- CYP24A1 | c.574G>A p.E192K | Missense Mutation (SNP) | VAF 76/864 reads (9%) | SIFT tolerated (0.58); PolyPhen benign (0.011); catalogued as rs1446673603; called by muse, mutect2
- CYP26A1 | c.674C>T p.P225L | Missense Mutation (SNP) | VAF 169/469 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99814901; called by muse, mutect2, varscan2
- CYP2B6 | c.1378G>A p.A460T | Missense Mutation (SNP) | VAF 77/721 reads (11%) | SIFT tolerated (0.07); PolyPhen benign (0.113); catalogued as rs747756796, COSV100137465; called by muse, mutect2, varscan2
- CYP2D6 | c.633G>T p.E211D | Missense Mutation (SNP) | VAF 388/1041 reads (37%) | SIFT tolerated (0.26); PolyPhen benign (0.01); catalogued as COSV100637302; called by muse, mutect2, varscan2
- CYP2D6 | c.501C>A p.H167Q | Missense Mutation (SNP) | VAF 466/1075 reads (43%) | SIFT tolerated (0.7); PolyPhen benign (0.001); catalogued as rs1135825, COSV62245219; called by muse, varscan2
- CYP2E1 | c.226C>T p.R76C | Missense Mutation (SNP) | VAF 22/662 reads (3%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs1329756728, COSV53314402; called by muse, mutect2
- CYP2R1 | c.1368G>T p.M456I | Missense Mutation (SNP) | VAF 49/1007 reads (5%) | SIFT tolerated (0.49); PolyPhen probably damaging (0.936); catalogued as COSV100584913; called by muse, mutect2
- CYP7B1 | c.1322C>T p.P441L | Missense Mutation (SNP) | VAF 397/934 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1376071051, CM166063, COSV59586966; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- DAPK3 | c.610G>A p.G204S | Missense Mutation (SNP) | VAF 148/365 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs947452629; called by muse, mutect2, varscan2
- DAZL | c.664G>A p.G222R | Missense Mutation (SNP) | VAF 91/808 reads (11%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.988); catalogued as rs1204021688; called by muse, mutect2, varscan2
- DBF4B | c.1198G>T p.G400C | Missense Mutation (SNP) | VAF 88/170 reads (52%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.894); catalogued as COSV59259681; called by muse, mutect2, varscan2
- DCAF15 | c.634C>A p.L212I | Missense Mutation (SNP) | VAF 32/561 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.932); catalogued as COSV54335467; called by muse, mutect2
- DDC | c.681G>T p.E227D | Missense Mutation (SNP) | VAF 277/656 reads (42%) | SIFT tolerated (0.23); PolyPhen benign (0.006); catalogued as COSV63565136; called by muse, mutect2, varscan2
- DDR1 | c.1819C>T p.R607* (on ENST00000324771; = p.R570* on NM_001954.4) | Nonsense Mutation (SNP) | VAF 83/238 reads (35%) | catalogued as rs1055137436; called by muse, mutect2, varscan2
- DDRGK1 | c.487C>A p.L163I | Missense Mutation (SNP) | VAF 219/487 reads (45%) | SIFT tolerated (0.38); PolyPhen benign (0.056); catalogued as COSV63227337; called by muse, mutect2, varscan2
- DDX28 | c.735G>T p.R245S | Missense Mutation (SNP) | VAF 233/579 reads (40%) | SIFT tolerated (0.98); PolyPhen benign (0.006); catalogued as COSV100193182; called by muse, mutect2, varscan2
- DDX60L | c.4925del p.N1642Mfs*9 | Frame Shift Del (DEL) | VAF 170/420 reads (40%) | catalogued as rs773554787; called by mutect2, varscan2
- DDX60L | c.1243C>A p.L415M | Missense Mutation (SNP) | VAF 50/950 reads (5%) | SIFT deleterious (0.03); PolyPhen benign (0.382); catalogued as COSV52709764; called by muse, mutect2
- DENND1B | c.1002G>T p.Q334H | Missense Mutation (SNP) | VAF 505/1334 reads (38%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.519); catalogued as COSV52471765; called by muse, mutect2, varscan2
- DENND4A | c.3484G>A p.D1162N | Missense Mutation (SNP) | VAF 141/855 reads (16%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.631); catalogued as rs1473505616; called by muse, mutect2, varscan2
- DGCR2 | c.157G>T p.G53C | Missense Mutation (SNP) | VAF 55/1290 reads (4%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV99593521; called by muse, mutect2
- DGKK | c.1583G>T p.G528V | Missense Mutation (SNP) | VAF 232/275 reads (84%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV101052882; called by muse, mutect2, varscan2
- DIAPH3 | c.3055del p.R1019Efs*12 (on ENST00000400324 / NM_001042517.2; = p.R756Efs*12 on NM_030932.3) | Frame Shift Del (DEL) | VAF 216/599 reads (36%) | catalogued as rs753024929; called by mutect2, varscan2
- DIAPH3 | c.1813C>T p.P605S (on ENST00000400324 / NM_001042517.2; = p.P342S on NM_030932.3) | Missense Mutation (SNP) | VAF 166/373 reads (45%) | SIFT tolerated (0.12); PolyPhen benign (0.086); catalogued as rs746295750; called by muse, mutect2, varscan2
- DISP2 | c.2498C>A p.P833H | Missense Mutation (SNP) | VAF 112/313 reads (36%) | SIFT tolerated (0.28); PolyPhen possibly damaging (0.891); catalogued as rs773882120; called by muse, mutect2, varscan2
- DNAAF5 | c.1771G>A p.V591I | Missense Mutation (SNP) | VAF 271/648 reads (42%) | SIFT tolerated (0.54); PolyPhen benign (0.003); catalogued as rs754002298, COSV52416019; called by muse, varscan2
- DNAH1 | c.10328G>A p.R3443H | Missense Mutation (SNP) | VAF 151/421 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as rs752391361, COSV70226372; called by muse, mutect2, varscan2
- DNAH11 | c.4537G>A p.E1513K | Missense Mutation (SNP) | VAF 373/1027 reads (36%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.883); catalogued as rs758252527; called by muse, mutect2, varscan2
- DNAH14 | c.6091G>A p.D2031N (on ENST00000445597; = p.D2684N on NM_001367479.1) | Missense Mutation (SNP) | VAF 38/1104 reads (3%) | SIFT tolerated (0.27); PolyPhen benign (0.033); catalogued as COSV59904130; called by muse, mutect2
- DNAH7 | c.3808C>A p.L1270I | Missense Mutation (SNP) | VAF 174/554 reads (31%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.957); catalogued as COSV100417651; called by muse, mutect2, varscan2
- DNAH9 | c.253C>T p.P85S | Missense Mutation (SNP) | VAF 169/447 reads (38%) | SIFT tolerated (0.11); PolyPhen benign (0.001); catalogued as rs762990165; called by muse, mutect2, varscan2
- DNAH9 | c.11158G>A p.D3720N | Missense Mutation (SNP) | VAF 32/910 reads (4%) | SIFT tolerated (0.41); PolyPhen benign (0); catalogued as rs1567880061, COSV99306143; called by muse, mutect2
- DNAJB11 | c.550C>T p.R184C | Missense Mutation (SNP) | VAF 348/894 reads (39%) | SIFT tolerated (0.06); PolyPhen benign (0.12); catalogued as rs1462006657, COSV54002755; called by muse, varscan2
- DNAJB2 | c.74G>A p.R25H | Missense Mutation (SNP) | VAF 20/360 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.714); catalogued as rs1403156116, COSV60677912; called by muse, mutect2
- DNAJC6 | c.1148C>T p.T383I | Missense Mutation (SNP) | VAF 282/819 reads (34%) | SIFT tolerated (0.4); PolyPhen benign (0.01); catalogued as rs138800944; called by muse, mutect2, varscan2
- DNHD1 | c.7669C>T p.R2557C | Missense Mutation (SNP) | VAF 25/694 reads (4%) | SIFT deleterious (0.03); PolyPhen benign (0.376); catalogued as rs901692242; called by muse, mutect2
- DNM3 | c.1235T>C p.I412T | Missense Mutation (SNP) | VAF 39/1071 reads (4%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.994); catalogued as rs1282138603; called by muse, mutect2
- DNMBP | c.2413A>G p.M805V | Missense Mutation (SNP) | VAF 52/1147 reads (5%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.714); catalogued as rs1015377728; called by muse, mutect2
- DOCK10 | c.5563G>A p.D1855N | Missense Mutation (SNP) | VAF 402/968 reads (42%) | SIFT tolerated (0.91); PolyPhen benign (0.003); catalogued as rs1439819659; called by muse, mutect2, varscan2
- DOCK10 | c.2596G>T p.E866* | Nonsense Mutation (SNP) | VAF 340/817 reads (42%) | catalogued as COSV99291643; called by muse, mutect2, varscan2
- DOCK5 | c.5466dup p.K1823Qfs*6 | Frame Shift Ins (INS) | VAF 242/626 reads (39%) | catalogued as rs34013556; called by mutect2, varscan2
- DOK6 | c.434C>A p.P145H | Missense Mutation (SNP) | VAF 37/579 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1416452342, COSV101234972; called by muse, mutect2
- DOP1A | c.1426G>A p.V476M | Missense Mutation (SNP) | VAF 401/1155 reads (35%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.971); catalogued as COSV52706268; called by muse, mutect2, varscan2
- DPF2 | c.966G>T p.W322C | Missense Mutation (SNP) | VAF 136/856 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52889228; called by mutect2, varscan2
- DPF3 | c.1046del p.P349Rfs*? | Frame Shift Del (DEL) | VAF 176/438 reads (40%) | catalogued as rs1567177829; called by mutect2, varscan2
- DPF3 | c.421G>T p.E141* | Nonsense Mutation (SNP) | VAF 85/231 reads (37%) | catalogued as COSV63498695; called by muse, mutect2, varscan2
- DPH1 | c.623C>T p.P208L | Missense Mutation (SNP) | VAF 66/790 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.566); catalogued as rs1358202828; called by muse, mutect2
- DPP7 | c.1336G>A p.D446N | Missense Mutation (SNP) | VAF 41/545 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs368784110; called by muse, mutect2
- DPY19L4 | c.593C>T p.A198V | Missense Mutation (SNP) | VAF 216/606 reads (36%) | SIFT tolerated (0.87); PolyPhen benign (0.04); catalogued as rs754321957; called by muse, mutect2, varscan2
- DROSHA | c.3902C>A p.A1301D | Missense Mutation (SNP) | VAF 291/874 reads (33%) | SIFT deleterious (0); PolyPhen benign (0.298); catalogued as COSV60782207; called by muse, mutect2, varscan2
- DTL | c.1531T>G p.S511A | Missense Mutation (SNP) | VAF 348/967 reads (36%) | SIFT deleterious (0.04); PolyPhen benign (0.174); catalogued as rs748049547; called by muse, mutect2, varscan2
- DUOXA2 | c.446G>A p.G149E | Missense Mutation (SNP) | VAF 139/388 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs762481523; called by muse, mutect2, varscan2
- DYRK1B | c.1633del p.Q545Sfs*19 | Frame Shift Del (DEL) | VAF 132/329 reads (40%) | catalogued as rs775499198; called by mutect2, varscan2
- E2F4 | c.1207T>C p.C403R | Missense Mutation (SNP) | VAF 30/763 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV62607389; called by muse, mutect2
- EBF1 | c.454C>T p.R152* | Nonsense Mutation (SNP) | VAF 44/860 reads (5%) | catalogued as COSV100566271; called by muse, mutect2
- EBLN1 | c.412C>T p.R138C | Missense Mutation (SNP) | VAF 359/786 reads (46%) | SIFT tolerated (0.09); PolyPhen benign (0); catalogued as rs1016283175; called by muse, mutect2, varscan2
- ECHDC3 | c.668T>C p.V223A | Missense Mutation (SNP) | VAF 46/758 reads (6%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.68); catalogued as rs985708471; called by muse, mutect2
- EDA | c.525G>T p.K175N | Missense Mutation (SNP) | VAF 13/256 reads (5%) | SIFT deleterious, low confidence (0.05); PolyPhen probably damaging (0.987); catalogued as COSV100999829; called by muse, mutect2
- EDEM1 | c.1417C>T p.P473S | Missense Mutation (SNP) | VAF 315/761 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99849058; called by muse, mutect2, varscan2
- EFL1 | c.422C>T p.P141L | Missense Mutation (SNP) | VAF 66/848 reads (8%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.841); catalogued as rs753870596; called by muse, mutect2
- EGFR | c.1352G>A p.R451H | Missense Mutation (SNP) | VAF 263/742 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs751667594, COSV51842976; called by muse, mutect2, varscan2
- EGR4 | c.1574G>T p.S525I (on ENST00000545030; = p.S422I on NM_001965.4) | Missense Mutation (SNP) | VAF 40/936 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1244510948, COSV71532006; called by muse, mutect2
- EHBP1L1 | c.3173G>A p.R1058H | Missense Mutation (SNP) | VAF 284/727 reads (39%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.938); catalogued as rs774355413, COSV58573693; called by muse, mutect2, varscan2
- EIF4A3 | c.515G>A p.R172H | Missense Mutation (SNP) | VAF 315/742 reads (42%) | SIFT deleterious (0); PolyPhen benign (0.333); catalogued as rs1247723909; called by muse, mutect2, varscan2
- ELAC2 | c.1888C>T p.R630* | Nonsense Mutation (SNP) | VAF 261/622 reads (42%) | catalogued as rs781680309; called by muse, mutect2, varscan2
- ELL3 | c.867G>A p.L289= | Splice Region (SNP) | VAF 175/499 reads (35%) | catalogued as COSV100082656; called by muse, mutect2, varscan2
- ELMO2 | c.756G>T p.Q252H | Missense Mutation (SNP) | VAF 133/896 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.885); catalogued as COSV99281525; called by muse, mutect2, varscan2
- EME2 | c.884G>T p.R295M | Missense Mutation (SNP) | VAF 100/291 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV51598956; called by muse, varscan2
- EMILIN1 | c.1059C>A p.C353* | Nonsense Mutation (SNP) | VAF 17/331 reads (5%) | catalogued as COSV53154393; called by muse, mutect2
- ENAH | c.1061C>T p.P354L | Missense Mutation (SNP) | VAF 193/438 reads (44%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.991); catalogued as rs752063989; called by muse, mutect2, varscan2
- ENAM | c.1645C>T p.P549S | Missense Mutation (SNP) | VAF 315/790 reads (40%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.615); catalogued as rs762086399; called by muse, mutect2, varscan2
- ENO4 | c.1007C>T p.P336L (on ENST00000622726; = p.P333L on NM_001242699.2) | Missense Mutation (SNP) | VAF 36/881 reads (4%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.897); catalogued as rs1287709831; called by muse, mutect2
- EP400 | c.4022G>T p.R1341L | Missense Mutation (SNP) | VAF 228/473 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV57769676; called by muse, mutect2, varscan2
- EPB42 | c.1369G>A p.E457K (on ENST00000441366 / NM_001114134.2; = p.E487K on NM_000119.3) | Missense Mutation (SNP) | VAF 240/606 reads (40%) | SIFT tolerated (0.88); PolyPhen benign (0); catalogued as COSV55750836; called by muse, mutect2, varscan2
- EPHA10 | c.1100G>A p.G367D | Missense Mutation (SNP) | VAF 40/316 reads (13%) | SIFT deleterious (0.01); PolyPhen benign (0.001); catalogued as rs1351419598; called by muse, mutect2, varscan2
- EPHA2 | c.1790C>A p.P597H | Missense Mutation (SNP) | VAF 57/1329 reads (4%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV100626019; called by muse, mutect2
- EPHB2 | c.1566G>T p.K522N | Missense Mutation (SNP) | VAF 320/767 reads (42%) | SIFT tolerated (0.2); PolyPhen benign (0.104); catalogued as COSV101007321; called by muse, mutect2, varscan2
- EPHB2 | c.2582A>G p.D861G (on ENST00000400191 / NM_001309193.2; = p.D862G on NM_004442.7) | Missense Mutation (SNP) | VAF 238/666 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.96); catalogued as rs1285652571; called by muse, mutect2, varscan2
- EPHB4 | c.2788G>T p.A930S | Missense Mutation (SNP) | VAF 330/895 reads (37%) | SIFT tolerated (0.43); PolyPhen benign (0.294); catalogued as COSV100639432; called by muse, mutect2, varscan2
- EPHB6 | c.484G>A p.E162K | Missense Mutation (SNP) | VAF 461/1098 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs763526105, COSV67420259; called by muse, varscan2
- ERBB4 | c.1465G>A p.D489N | Missense Mutation (SNP) | VAF 64/998 reads (6%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV53588591; called by muse, mutect2
- ERGIC1 | c.757A>G p.I253V | Missense Mutation (SNP) | VAF 197/526 reads (37%) | SIFT deleterious (0.02); PolyPhen benign (0.009); catalogued as rs983559998, COSV67128954; called by muse, mutect2, varscan2
- ESRRB | c.76G>A p.G26S | Missense Mutation (SNP) | VAF 164/461 reads (36%) | SIFT tolerated, low confidence (0.85); PolyPhen benign (0.024); catalogued as rs1230481775; called by muse, mutect2, varscan2
- EVC | c.1777-1G>T p.X593_splice | Splice Site (SNP) | VAF 14/236 reads (6%) | catalogued as CS131170; called by muse, mutect2
- EVC2 | c.335C>A p.P112Q | Missense Mutation (SNP) | VAF 60/836 reads (7%) | SIFT deleterious (0.03); PolyPhen benign (0.024); catalogued as COSV100186023; called by muse, mutect2
- EWSR1 | c.1337G>A p.R446Q | Missense Mutation (SNP) | VAF 227/608 reads (37%) | SIFT tolerated (0.28); PolyPhen benign (0.057); catalogued as rs200670756, COSV58422860; called by muse, mutect2, varscan2
- EXO1 | c.347G>A p.R116Q | Missense Mutation (SNP) | VAF 511/1345 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.552); catalogued as rs371763760, COSV100800264; called by muse, mutect2, varscan2
- EYS | c.8296G>T p.G2766C (on ENST00000370621 / NM_001292009.1; = p.G2745C on NM_001142800.2) | Missense Mutation (SNP) | VAF 285/722 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV65481689; called by muse, mutect2, varscan2
- F8 | c.5815G>T p.A1939S | Missense Mutation (SNP) | VAF 68/223 reads (30%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.971); catalogued as CM020130; called by muse, mutect2, varscan2
- F8 | c.3874G>A p.E1292K | Missense Mutation (SNP) | VAF 473/566 reads (84%) | SIFT tolerated (0.24); PolyPhen benign (0); catalogued as CD0911178; called by muse, mutect2, varscan2
- FAAH2 | c.732G>T p.K244N | Missense Mutation (SNP) | VAF 189/231 reads (82%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV66507993; called by muse, mutect2, varscan2
- FAM177B | c.339G>T p.K113N | Missense Mutation (SNP) | VAF 285/803 reads (35%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.876); catalogued as COSV62600940; called by muse, mutect2, varscan2
- FAM189A1 | c.791G>T p.R264M | Missense Mutation (SNP) | VAF 228/582 reads (39%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV99724028; called by muse, varscan2
- FAM20A | c.1264del p.D422Mfs*33 | Frame Shift Del (DEL) | VAF 318/738 reads (43%) | catalogued as rs1315218764, COSV56837183; called by mutect2, varscan2
- FAM3B | c.485+1G>A p.X162_splice | Splice Site (SNP) | VAF 241/694 reads (35%) | catalogued as rs1320133462; called by muse, mutect2, varscan2
- FAM83F | c.1454-1G>T p.X485_splice | Splice Site (SNP) | VAF 218/472 reads (46%) | catalogued as COSV60999579; called by muse, mutect2, varscan2
- FASTK | c.752G>T p.R251L | Missense Mutation (SNP) | VAF 123/373 reads (33%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.705); catalogued as COSV99879662; called by muse, mutect2, varscan2
- FAT1 | c.7175A>G p.Q2392R | Missense Mutation (SNP) | VAF 38/828 reads (5%) | SIFT deleterious (0.01); PolyPhen benign (0.424); catalogued as rs1247867395; called by muse, mutect2
- FAT3 | c.3059C>A p.S1020Y | Missense Mutation (SNP) | VAF 313/784 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.957); catalogued as COSV53150605; called by mutect2, varscan2
- FAT3 | c.3865G>A p.A1289T | Missense Mutation (SNP) | VAF 48/600 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.562); catalogued as rs776813948, COSV53178736; called by muse, mutect2
- FBN3 | c.3545G>T p.G1182V | Missense Mutation (SNP) | VAF 28/566 reads (5%) | SIFT tolerated (0.26); PolyPhen probably damaging (0.913); catalogued as COSV54458576; called by muse, mutect2
- FBN3 | c.2259dup p.G754Rfs*69 | Frame Shift Ins (INS) | VAF 127/356 reads (36%) | catalogued as rs755836480; called by mutect2, varscan2
- FBRS | c.1370G>A p.R457Q (on ENST00000287468; = p.R977Q on NM_001105079.3) | Missense Mutation (SNP) | VAF 211/513 reads (41%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.005); catalogued as rs555016305; called by muse, mutect2, varscan2
- FBRSL1 | c.876del p.A293Pfs*121 | Frame Shift Del (DEL) | VAF 52/128 reads (41%) | catalogued as rs1461432773; called by mutect2, varscan2
- FCGR1B | c.562+4T>A | Splice Region (SNP) | VAF 24/631 reads (4%) | catalogued as rs1263300899; called by muse, mutect2
- FCRL3 | c.2038A>G p.M680V | Missense Mutation (SNP) | VAF 90/839 reads (11%) | SIFT tolerated (0.26); PolyPhen benign (0.001); catalogued as rs757521851; called by muse, mutect2, varscan2
- FER1L5 | c.3558C>T p.G1186= (on ENST00000623019; = p.G1159= on NM_001293083.2) | Splice Region (SNP) | VAF 191/438 reads (44%) | catalogued as COSV101208885; called by muse, mutect2, varscan2
- FER1L6 | c.19A>G p.K7E | Missense Mutation (SNP) | VAF 48/936 reads (5%) | SIFT deleterious, low confidence (0.03); PolyPhen probably damaging (0.971); catalogued as COSV67550728, COSV67553294; called by muse, mutect2
- FFAR4 | c.411G>T p.M137I | Missense Mutation (SNP) | VAF 30/559 reads (5%) | SIFT tolerated (0.07); PolyPhen benign (0.037); catalogued as rs1481179097; called by muse, mutect2
- FHIT | c.335G>A p.S112N | Missense Mutation (SNP) | VAF 244/685 reads (36%) | SIFT tolerated (0.29); PolyPhen benign (0); catalogued as rs768734343; called by muse, mutect2, varscan2
- FKBP6 | c.265+4G>T | Splice Region (SNP) | VAF 273/704 reads (39%) | catalogued as COSV52722799; called by muse, mutect2, varscan2
- FLG2 | c.6806A>G p.H2269R | Missense Mutation (SNP) | VAF 280/777 reads (36%) | SIFT tolerated (0.53); PolyPhen probably damaging (0.979); catalogued as rs1475012172; called by muse, mutect2, varscan2
- FMR1 | c.1660G>A p.D554N | Missense Mutation (SNP) | VAF 32/462 reads (7%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.856); catalogued as rs782041975; called by muse, mutect2
- FN1 | c.340C>T p.R114C | Missense Mutation (SNP) | VAF 359/974 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV60552373; called by muse, mutect2, varscan2
- FOXD4 | c.901C>A p.L301I | Missense Mutation (SNP) | VAF 85/843 reads (10%) | SIFT tolerated (0.23); PolyPhen benign (0.009); catalogued as rs1225666357; called by muse, mutect2, varscan2
- FOXL2 | c.108G>T p.K36N | Missense Mutation (SNP) | VAF 188/486 reads (39%) | SIFT tolerated (0.36); PolyPhen benign (0.074); catalogued as COSV100374904; called by muse, mutect2, varscan2
- FREM1 | c.2641-1G>T p.X881_splice | Splice Site (SNP) | VAF 182/383 reads (48%) | catalogued as COSV66524397; called by muse, mutect2, varscan2
- FRRS1L | c.665A>G p.H222R | Missense Mutation (SNP) | VAF 60/788 reads (8%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.994); catalogued as rs370416513; called by muse, mutect2
- FUT11 | c.947C>T p.P316L | Missense Mutation (SNP) | VAF 48/725 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1173364276; called by muse, mutect2
- FYCO1 | c.55G>T p.D19Y | Missense Mutation (SNP) | VAF 207/566 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56118514; called by muse, mutect2, varscan2
- GABRG1 | c.1235G>A p.C412Y | Missense Mutation (SNP) | VAF 359/973 reads (37%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.781); catalogued as rs749987948; called by muse, mutect2, varscan2
- GAL3ST2 | c.784G>A p.A262T | Missense Mutation (SNP) | VAF 114/265 reads (43%) | SIFT tolerated (0.58); PolyPhen benign (0); catalogued as rs775970290; called by muse, mutect2, varscan2
- GALNT11 | c.1555C>A p.Q519K | Missense Mutation (SNP) | VAF 27/541 reads (5%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.735); catalogued as rs1246888872; called by muse, mutect2
- GAPVD1 | c.1436C>A p.P479H | Missense Mutation (SNP) | VAF 240/592 reads (41%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as rs1467337538; called by mutect2, varscan2
- GATD1 | c.217G>A p.A73T | Missense Mutation (SNP) | VAF 213/515 reads (41%) | SIFT deleterious (0); PolyPhen benign (0.337); catalogued as rs754507993; called by muse, mutect2, varscan2
- GDF1 | c.865C>T p.R289C | Missense Mutation (SNP) | VAF 24/484 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV53203431; called by muse, mutect2
- GGT6 | c.1210C>T p.L404F (on ENST00000574154 / NM_001122890.3; = p.L372F on NM_153338.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 26/798 reads (3%) | SIFT tolerated (0.07); PolyPhen benign (0.007); catalogued as COSV54604447; called by muse, mutect2
- GID8 | c.137C>T p.A46V | Missense Mutation (SNP) | VAF 243/662 reads (37%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.995); catalogued as rs1362823185; called by muse, mutect2, varscan2
- GIMAP6 | c.505G>A p.A169T | Missense Mutation (SNP) | VAF 22/328 reads (7%) | SIFT tolerated (0.14); PolyPhen benign (0.215); catalogued as rs1010565765, COSV61034154; called by muse, mutect2
- GIMAP6 | c.29C>T p.P10L | Missense Mutation (SNP) | VAF 244/708 reads (34%) | SIFT tolerated (0.66); PolyPhen benign (0); catalogued as rs1268662540, COSV100188238; called by muse, mutect2, varscan2
- GJC1 | c.409G>A p.D137N | Missense Mutation (SNP) | VAF 27/805 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.928); catalogued as rs1430531784; called by muse, mutect2
- GK | c.852-1G>T p.X284_splice (on ENST00000427190 / NM_001205019.2; = p.X278_splice on NM_000167.6) | Splice Site (SNP) | VAF 27/328 reads (8%) | catalogued as CS033120; called by muse, mutect2
- GLDC | c.2302G>T p.G768W | Missense Mutation (SNP) | VAF 62/1632 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100393873; called by muse, mutect2
- GLI1 | c.1978C>A p.L660M | Missense Mutation (SNP) | VAF 212/508 reads (42%) | SIFT tolerated (0.34); PolyPhen probably damaging (0.996); catalogued as COSV57362107; called by muse, mutect2, varscan2
- GLI3 | c.1870C>A p.L624I | Missense Mutation (SNP) | VAF 233/574 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV67886715; called by mutect2, varscan2
- GLIS1 | c.344del p.G115Afs*31 | Frame Shift Del (DEL) | VAF 192/539 reads (36%) | catalogued as COSV100389202; called by mutect2, varscan2
- GNAI3 | c.527G>A p.R176Q | Missense Mutation (SNP) | VAF 313/888 reads (35%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.9); catalogued as rs765776409; called by muse, mutect2, varscan2
- GNL1 | c.1446G>A p.W482* | Nonsense Mutation (SNP) | VAF 34/376 reads (9%) | catalogued as COSV64921353; called by muse, mutect2
- GOLGA4 | c.6459del p.T2154Hfs*33 | Frame Shift Del (DEL) | VAF 196/571 reads (34%) | catalogued as COSV100729179; called by mutect2, varscan2
- GOLGA6L2 | c.2687C>T p.A896V | Missense Mutation (SNP) | VAF 122/332 reads (37%) | SIFT deleterious, low confidence (0); catalogued as rs565521161; called by muse, mutect2, varscan2
- GOLGA8M | c.1331C>A p.P444Q | Missense Mutation (SNP) | VAF 10/16 reads (63%) | SIFT tolerated (0.06); PolyPhen benign (0.051); catalogued as COSV61013597; called by mutect2, varscan2
- GON4L | c.5319C>A p.F1773L | Missense Mutation (SNP) | VAF 435/1100 reads (40%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.97); catalogued as COSV55186418; called by muse, mutect2, varscan2
- GPA33 | c.394C>T p.R132C | Missense Mutation (SNP) | VAF 73/709 reads (10%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); catalogued as rs765785862; ClinVar: likely benign; called by muse, mutect2, varscan2
- GPATCH3 | c.214G>A p.A72T | Missense Mutation (SNP) | VAF 32/612 reads (5%) | SIFT tolerated (0.25); PolyPhen benign (0.051); catalogued as COSV100658891; called by muse, mutect2
- GPR52 | c.179C>T p.T60I | Missense Mutation (SNP) | VAF 56/995 reads (6%) | SIFT tolerated (0.86); PolyPhen benign (0.013); catalogued as COSV52284326; called by muse, mutect2
- GPR6 | c.502C>A p.L168M | Missense Mutation (SNP) | VAF 131/340 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV51572036; called by muse, mutect2, varscan2
- GRB7 | c.513G>A p.W171* | Nonsense Mutation (SNP) | VAF 222/613 reads (36%) | catalogued as COSV58451368; called by muse, mutect2, varscan2
- GRB7 | c.625G>T p.D209Y | Missense Mutation (SNP) | VAF 47/629 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.902); catalogued as COSV58446177; called by muse, mutect2
- GREB1 | c.734G>T p.G245V | Missense Mutation (SNP) | VAF 315/816 reads (39%) | SIFT deleterious (0.03); PolyPhen benign (0.003); catalogued as COSV99302687; called by muse, mutect2, varscan2
- GRID2IP | c.2326G>T p.G776C | Missense Mutation (SNP) | VAF 200/556 reads (36%) | SIFT tolerated (0.2); PolyPhen benign (0.219); catalogued as rs1306704676; called by muse, mutect2, varscan2
- GRIK2 | c.2603C>A p.S868Y | Missense Mutation (SNP) | VAF 326/772 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.883); catalogued as COSV59740380; called by muse, mutect2, varscan2
- GRIN2A | c.21G>A p.W7* | Nonsense Mutation (SNP) | VAF 184/492 reads (37%) | catalogued as rs1555491563; called by muse, varscan2
- GSG1 | c.306del p.F103Sfs*83 (on ENST00000651961 / NM_001080555.4; = p.F90Sfs*61 on NM_031289.5) | Frame Shift Del (DEL) | VAF 166/486 reads (34%) | catalogued as COSV60971718; called by mutect2, varscan2
- GTF2IRD2 | c.1621dup p.I541Nfs*13 | Frame Shift Ins (INS) | VAF 20/52 reads (38%) | catalogued as rs782041498; called by mutect2, varscan2
- GTF3C1 | c.1120G>A p.D374N | Missense Mutation (SNP) | VAF 154/412 reads (37%) | SIFT deleterious (0.04); PolyPhen benign (0.009); catalogued as rs1010005506, COSV100649574; called by muse, varscan2
- GTF3C2 | c.1117C>T p.R373* | Nonsense Mutation (SNP) | VAF 145/371 reads (39%) | catalogued as COSV53125771; called by muse, mutect2, varscan2
- GTPBP4 | c.1579C>A p.L527I | Missense Mutation (SNP) | VAF 164/431 reads (38%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.87); catalogued as COSV52987081, COSV52987258; called by muse, mutect2, varscan2
- GUCY2C | c.587G>A p.G196D | Missense Mutation (SNP) | VAF 33/823 reads (4%) | SIFT tolerated (0.46); PolyPhen benign (0.001); catalogued as rs1303224468, COSV53795091; called by muse, mutect2
- GYPA | c.392C>A p.P131H | Missense Mutation (SNP) | VAF 280/811 reads (35%) | SIFT tolerated (0.29); PolyPhen possibly damaging (0.847); catalogued as COSV99302335; called by muse, mutect2, varscan2
- HCAR3 | c.242C>T p.P81L | Missense Mutation (SNP) | VAF 231/628 reads (37%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.991); catalogued as rs757339733, COSV100811634, COSV63675712; called by muse, mutect2, varscan2
- HDAC4 | c.1941dup p.T648Hfs*12 | Frame Shift Ins (INS) | VAF 334/771 reads (43%) | catalogued as rs1319111506; called by mutect2, varscan2
- HDAC4 | c.37C>T p.R13* | Nonsense Mutation (SNP) | VAF 215/600 reads (36%) | catalogued as rs1336002481, COSV61868169; called by muse, mutect2, varscan2
- HEATR3 | c.1660G>A p.G554R | Missense Mutation (SNP) | VAF 399/968 reads (41%) | SIFT tolerated (0.22); PolyPhen benign (0.013); catalogued as rs1251681451; called by muse, mutect2, varscan2
- HEATR5B | c.457C>T p.R153* | Nonsense Mutation (SNP) | VAF 209/593 reads (35%) | catalogued as rs1291080607, COSV51859314; called by muse, mutect2, varscan2
- HEATR6 | c.241C>T p.Q81* | Nonsense Mutation (SNP) | VAF 365/949 reads (38%) | catalogued as rs1348789005; called by muse, mutect2, varscan2
- HECTD4 | c.2153G>A p.R718H | Missense Mutation (SNP) | VAF 58/787 reads (7%) | SIFT tolerated (0.11); PolyPhen benign (0.027); catalogued as rs200610721; called by muse, mutect2
- HERC2 | c.14200G>A p.A4734T | Missense Mutation (SNP) | VAF 193/545 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.934); catalogued as rs1175518080, COSV55312027; called by muse, mutect2, varscan2
- HERC2 | c.4001C>T p.A1334V | Missense Mutation (SNP) | VAF 271/725 reads (37%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.956); catalogued as rs1201312472, COSV99875167; called by muse, mutect2, varscan2
- HEXB | c.96G>T p.Q32H | Missense Mutation (SNP) | VAF 112/319 reads (35%) | SIFT tolerated (0.29); PolyPhen benign (0.26); catalogued as rs868106940; called by muse, mutect2, varscan2
- HIP1R | c.2275G>A p.G759S | Missense Mutation (SNP) | VAF 150/376 reads (40%) | SIFT tolerated (0.45); PolyPhen benign (0.001); catalogued as rs781331033; called by muse, mutect2, varscan2
- HKDC1 | c.2306G>T p.G769V | Missense Mutation (SNP) | VAF 44/794 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV100664844; called by muse, mutect2
- HMGN4 | c.248C>T p.A83V | Missense Mutation (SNP) | VAF 180/513 reads (35%) | SIFT deleterious (0.04); PolyPhen benign (0.022); catalogued as rs977718384; called by muse, mutect2, varscan2
- HNRNPA1 | c.1063+6G>A | Splice Region (SNP) | VAF 174/470 reads (37%) | catalogued as rs543402803; called by muse, mutect2, varscan2
- HR | c.2121+2T>C p.X707_splice | Splice Site (SNP) | VAF 26/418 reads (6%) | catalogued as CS056756; called by muse, mutect2
- HRC | c.310C>T p.P104S | Missense Mutation (SNP) | VAF 123/278 reads (44%) | SIFT deleterious (0.04); PolyPhen benign (0.003); catalogued as COSV53257481; called by muse, mutect2, varscan2
- HRNR | c.5876G>T p.G1959V | Missense Mutation (SNP) | VAF 128/478 reads (27%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.543); catalogued as COSV64258944; called by muse, mutect2, varscan2
- HS3ST2 | c.670G>A p.D224N | Missense Mutation (SNP) | VAF 221/581 reads (38%) | SIFT deleterious (0.05); PolyPhen benign (0.062); catalogued as rs533578919; called by muse, mutect2, varscan2
- HSF5 | c.1777G>T p.E593* | Nonsense Mutation (SNP) | VAF 43/1018 reads (4%) | catalogued as COSV104406279; called by muse, mutect2
- HSPA4L | c.1906G>A p.G636S | Missense Mutation (SNP) | VAF 307/826 reads (37%) | SIFT tolerated (0.52); PolyPhen benign (0.021); catalogued as rs1219623515; called by muse, mutect2, varscan2
- HSPA8 | c.1392A>G p.I464M | Missense Mutation (SNP) | VAF 237/651 reads (36%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.978); catalogued as COSV57086120; called by muse, mutect2, varscan2
- HSPG2 | c.11899C>A p.L3967M | Missense Mutation (SNP) | VAF 204/434 reads (47%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.798); catalogued as rs138413567; called by muse, varscan2
- HSPG2 | c.11441G>T p.S3814I | Missense Mutation (SNP) | VAF 38/383 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.915); catalogued as rs941395612; called by muse, mutect2, varscan2
- HTR3D | c.539G>T p.S180I (on ENST00000382489 / NM_001163646.2; = p.S132I on NM_001145143.1) | Missense Mutation (SNP) | VAF 28/642 reads (4%) | SIFT deleterious (0.01); PolyPhen benign (0.109); catalogued as COSV61913704; called by muse, mutect2
- HYAL2 | c.1318T>C p.W440R | Missense Mutation (SNP) | VAF 20/424 reads (5%) | SIFT tolerated (0.37); PolyPhen benign (0); catalogued as rs782404838; called by muse, mutect2
- HYDIN | c.5720A>C p.K1907T | Missense Mutation (SNP) | VAF 70/505 reads (14%) | SIFT deleterious (0.03); PolyPhen benign (0.354); catalogued as COSV59264231; called by muse, mutect2, varscan2
- IARS1 | c.3505C>A p.L1169I | Missense Mutation (SNP) | VAF 335/742 reads (45%) | SIFT tolerated, low confidence (0.38); PolyPhen benign (0.001); catalogued as rs1259829232; called by muse, mutect2, varscan2
- IFNLR1 | c.206G>A p.R69H | Missense Mutation (SNP) | VAF 326/817 reads (40%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.687); catalogued as rs374140475; called by muse, mutect2, varscan2
- IGDCC4 | c.541G>A p.V181M | Missense Mutation (SNP) | VAF 188/465 reads (40%) | SIFT tolerated (0.1); PolyPhen benign (0.076); catalogued as rs765397844; called by muse, mutect2, varscan2
- IGF2 | c.439G>A p.E147K (on ENST00000434045 / NM_001127598.3; = p.E91K on NM_000612.6) | Missense Mutation (SNP) | VAF 278/751 reads (37%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.475); catalogued as COSV56101232; called by muse, mutect2, varscan2
- IGFBP4 | c.397G>A p.A133T | Missense Mutation (SNP) | VAF 272/678 reads (40%) | SIFT tolerated (0.63); PolyPhen benign (0.003); catalogued as rs775881002; called by muse, varscan2
- IGFBP5 | c.738G>T p.K246N | Missense Mutation (SNP) | VAF 62/858 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs778636181; called by muse, mutect2
- IGFL3 | c.367C>A p.L123M | Missense Mutation (SNP) | VAF 39/574 reads (7%) | SIFT tolerated, low confidence (0.23); PolyPhen possibly damaging (0.635); catalogued as COSV100407908; called by muse, mutect2
- IGSF22 | c.*477T>G | Splice Region (SNP) | VAF 43/96 reads (45%) | catalogued as COSV55011212; called by muse, mutect2, varscan2
- IGSF9B | c.269C>T p.A90V | Missense Mutation (SNP) | VAF 195/596 reads (33%) | SIFT tolerated (1); PolyPhen benign (0.19); catalogued as rs1565447441; called by muse, mutect2, varscan2
- IKZF1 | c.727G>T p.E243* | Nonsense Mutation (SNP) | VAF 182/531 reads (34%) | catalogued as COSV58781791; called by muse, mutect2, varscan2
- ILF3 | c.2443C>T p.R815* | Nonsense Mutation (SNP) | VAF 44/441 reads (10%) | catalogued as COSV99140469; called by muse, mutect2
- INO80D | c.820A>G p.T274A | Missense Mutation (SNP) | VAF 48/495 reads (10%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as rs757064035, COSV68960261; called by muse, mutect2
- INO80E | c.355C>T p.P119S | Missense Mutation (SNP) | VAF 194/530 reads (37%) | SIFT tolerated (0.25); PolyPhen possibly damaging (0.685); catalogued as rs946242665, COSV54230948; called by muse, mutect2, varscan2
- INPP4A | c.2068A>G p.I690V (on ENST00000074304 / NM_001134224.1; = p.I651V on NM_001566.2 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 74/972 reads (8%) | SIFT tolerated (0.4); PolyPhen benign (0.02); catalogued as rs1436731316; called by muse, mutect2
- INSRR | c.2795C>T p.T932M | Missense Mutation (SNP) | VAF 250/687 reads (36%) | SIFT tolerated (0.89); PolyPhen benign (0); catalogued as rs760327047; called by mutect2, varscan2
- INTS3 | c.859G>T p.G287C | Missense Mutation (SNP) | VAF 181/1267 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.881); catalogued as COSV100016124; called by muse, mutect2, varscan2
- INTS5 | c.311G>A p.R104H | Missense Mutation (SNP) | VAF 50/710 reads (7%) | SIFT tolerated (0.13); PolyPhen benign (0.025); catalogued as rs1320631321, COSV57951695; called by muse, mutect2
- INTS6L | c.2576C>A p.S859* | Nonsense Mutation (SNP) | VAF 365/459 reads (80%) | catalogued as COSV100878053; called by muse, mutect2, varscan2
- IPMK | c.49C>T p.P17S | Missense Mutation (SNP) | VAF 284/689 reads (41%) | SIFT tolerated, low confidence (0.34); PolyPhen benign (0.041); catalogued as rs748319518; called by muse, mutect2, varscan2
- IPO8 | c.2588C>A p.P863H | Missense Mutation (SNP) | VAF 86/1118 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV56243392; called by muse, mutect2
- IRAG1 | c.230C>A p.P77H | Missense Mutation (SNP) | VAF 46/820 reads (6%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.89); catalogued as COSV70210043; called by muse, mutect2
- IRF7 | c.989del p.P330Qfs*13 (on ENST00000397566; = p.P317Qfs*13 on NM_001572.5) | Frame Shift Del (DEL) | VAF 128/290 reads (44%) | catalogued as rs1406681445; called by mutect2, varscan2
- ISL1 | c.835G>A p.A279T | Missense Mutation (SNP) | VAF 335/843 reads (40%) | SIFT tolerated (0.12); PolyPhen benign (0.184); catalogued as rs770127886; called by muse, mutect2, varscan2
- ITGA10 | c.3004C>A p.L1002I | Missense Mutation (SNP) | VAF 175/442 reads (40%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.93); catalogued as COSV65197848; called by muse, mutect2, varscan2
- ITIH2 | c.657G>T p.Q219H | Missense Mutation (SNP) | VAF 84/1082 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.889); catalogued as COSV64431842; called by muse, mutect2
- ITIH5 | c.1526G>A p.G509D | Missense Mutation (SNP) | VAF 82/867 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53675264, COSV99904887; called by muse, mutect2
- ITPKC | c.1352C>A p.P451H | Missense Mutation (SNP) | VAF 230/529 reads (43%) | SIFT deleterious (0.01); PolyPhen benign (0.44); catalogued as COSV99648978; called by muse, mutect2, varscan2
- IVNS1ABP | c.1807A>G p.T603A | Missense Mutation (SNP) | VAF 287/802 reads (36%) | SIFT tolerated (0.11); PolyPhen benign (0.001); catalogued as COSV62250600; called by muse, mutect2, varscan2
- JAK3 | c.2080G>A p.E694K | Missense Mutation (SNP) | VAF 254/652 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.866); catalogued as rs1009464631, CM012985, COSV101512990; called by muse, mutect2, varscan2
- JAM3 | c.92C>A p.A31D | Missense Mutation (SNP) | VAF 135/421 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.911); catalogued as COSV100137768; called by muse, mutect2, varscan2
- JPH2 | c.1964G>T p.R655L | Missense Mutation (SNP) | VAF 261/607 reads (43%) | SIFT tolerated (0.2); PolyPhen benign (0.018); catalogued as COSV100881561, COSV65901952; called by muse, mutect2, varscan2
- KALRN | c.7420C>A p.L2474I (on ENST00000360013 / NM_001024660.4; = p.L777I on NM_007064.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 61/779 reads (8%) | SIFT tolerated, low confidence (0.16); PolyPhen probably damaging (0.992); catalogued as COSV52265458; called by muse, mutect2
- KATNIP | c.1036G>T p.A346S | Missense Mutation (SNP) | VAF 25/744 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV55194707; called by muse, mutect2
- KAZN | c.781G>A p.A261T | Missense Mutation (SNP) | VAF 194/522 reads (37%) | SIFT tolerated (0.11); PolyPhen benign (0.048); catalogued as rs760870987, COSV63207549; called by muse, mutect2, varscan2
- KCMF1 | c.569C>T p.P190L | Missense Mutation (SNP) | VAF 307/803 reads (38%) | SIFT deleterious (0); PolyPhen benign (0.158); catalogued as COSV69053128, COSV69054510; called by muse, mutect2, varscan2
- KCNB2 | c.658G>A p.E220K | Missense Mutation (SNP) | VAF 496/1220 reads (41%) | SIFT tolerated (0.84); PolyPhen benign (0.011); catalogued as COSV73049127; called by muse, mutect2, varscan2
- KCNH6 | c.50C>T p.T17I | Missense Mutation (SNP) | VAF 43/362 reads (12%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.986); catalogued as rs1254332321; called by muse, mutect2, varscan2
- KCNK18 | c.901C>A p.L301I | Missense Mutation (SNP) | VAF 44/413 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.93); catalogued as rs747483367, COSV57972140; called by muse, mutect2, varscan2
- KCNQ2 | c.1324C>T p.R442C (on ENST00000359125 / NM_172107.4; = p.R414C on NM_004518.6) | Missense Mutation (SNP) | VAF 47/373 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.714); catalogued as rs1354411692; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- KCNQ5 | c.730C>T p.R244C | Missense Mutation (SNP) | VAF 408/1067 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1314919218, COSV59659088; called by muse, mutect2, varscan2
- KDM4D | c.176C>T p.A59V | Missense Mutation (SNP) | VAF 180/446 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); catalogued as COSV58634437; called by muse, varscan2
- KDR | c.574A>C p.I192L | Missense Mutation (SNP) | VAF 88/978 reads (9%) | SIFT tolerated (0.47); PolyPhen benign (0.039); catalogued as COSV55778493; called by muse, mutect2
- KHDC3L | c.360G>T p.K120N | Missense Mutation (SNP) | VAF 22/515 reads (4%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.682); catalogued as COSV100950368; called by muse, mutect2
- KIAA0232 | c.3545C>A p.S1182Y | Missense Mutation (SNP) | VAF 90/1178 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.911); catalogued as rs572591231, COSV100300732, COSV56927569; called by muse, mutect2
- KIAA0753 | c.587C>T p.P196L | Missense Mutation (SNP) | VAF 285/760 reads (38%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.986); catalogued as rs889213757, COSV63816957; called by muse, mutect2, varscan2
- KIAA0825 | c.1286C>T p.A429V | Missense Mutation (SNP) | VAF 390/1031 reads (38%) | SIFT deleterious (0.05); PolyPhen benign (0.02); catalogued as rs374186567; called by muse, mutect2, varscan2
- KIF1B | c.1426C>T p.R476C (on ENST00000377086 / NM_001365952.1; = p.R430C on NM_015074.3) | Missense Mutation (SNP) | VAF 264/601 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.927); catalogued as rs760014398; called by muse, mutect2, varscan2
- KIF20B | c.1105C>T p.R369C | Missense Mutation (SNP) | VAF 52/826 reads (6%) | SIFT deleterious (0.01); PolyPhen benign (0.018); catalogued as rs767920353; called by muse, mutect2
- KIF20B | c.1156C>T p.R386* | Nonsense Mutation (SNP) | VAF 67/1027 reads (7%) | catalogued as rs762636055; called by muse, mutect2
- KIF26B | c.4934C>T p.T1645M | Missense Mutation (SNP) | VAF 156/366 reads (43%) | SIFT tolerated (0.25); PolyPhen benign (0); catalogued as rs1462889450, COSV63639842; called by muse, mutect2, varscan2
- KIF26B | c.5837G>A p.R1946Q | Missense Mutation (SNP) | VAF 107/741 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.588); catalogued as rs374777159, COSV63645163; called by muse, mutect2, varscan2
- KIF3C | c.1494G>T p.E498D | Missense Mutation (SNP) | VAF 80/883 reads (9%) | SIFT tolerated (0.23); PolyPhen benign (0.003); catalogued as COSV53097476; called by muse, mutect2
- KIF5C | c.2759C>T p.A920V | Missense Mutation (SNP) | VAF 255/679 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.977); catalogued as rs773265771; called by muse, mutect2, varscan2
- KIF7 | c.1717G>A p.A573T | Missense Mutation (SNP) | VAF 146/408 reads (36%) | SIFT tolerated (0.78); PolyPhen benign (0); catalogued as rs369321011, COSV67998042; called by muse, mutect2, varscan2
- KIF7 | c.983C>A p.P328H | Missense Mutation (SNP) | VAF 195/478 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1567067501; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- KIFC3 | c.892C>T p.Q298* | Nonsense Mutation (SNP) | VAF 217/474 reads (46%) | catalogued as COSV65553723; called by muse, mutect2, varscan2
- KIRREL2 | c.1891C>A p.L631I | Missense Mutation (SNP) | VAF 140/362 reads (39%) | SIFT tolerated (0.12); PolyPhen benign (0); catalogued as rs1419976840, COSV52875100, COSV99383923; called by muse, mutect2, varscan2
- KLHL18 | c.2T>C p.M1? | Translation Start Site (SNP) | VAF 63/519 reads (12%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0); catalogued as rs934314305; called by muse, mutect2, varscan2
- KLHL25 | c.331G>A p.A111T | Missense Mutation (SNP) | VAF 104/281 reads (37%) | SIFT tolerated (0.58); PolyPhen benign (0); catalogued as rs775818150, COSV61994242; called by muse, mutect2, varscan2
- KLHL38 | c.802C>A p.P268T | Missense Mutation (SNP) | VAF 28/670 reads (4%) | SIFT tolerated (0.34); PolyPhen benign (0.003); catalogued as COSV100384742; called by muse, mutect2
- KMT2C | c.13488del p.F4496Lfs*21 | Frame Shift Del (DEL) | VAF 352/892 reads (39%) | catalogued as COSV51456416; called by mutect2, varscan2
- KRIT1 | c.3G>T p.M1? | Translation Start Site (SNP) | VAF 238/663 reads (36%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.01); catalogued as COSV56066881; called by muse, mutect2, varscan2
- KRT1 | c.715C>T p.R239* | Nonsense Mutation (SNP) | VAF 114/720 reads (16%) | catalogued as rs759244867; called by muse, mutect2, varscan2
- KRT10 | c.206del p.G69Afs*9 | Frame Shift Del (DEL) | VAF 156/1150 reads (14%) | catalogued as COSV54091485; called by mutect2, varscan2
- KRT73 | c.80del p.G27Afs*91 | Frame Shift Del (DEL) | VAF 199/504 reads (39%) | catalogued as rs771858764; called by mutect2, varscan2
- KRTAP11-1 | c.278C>T p.S93F | Missense Mutation (SNP) | VAF 229/683 reads (34%) | SIFT tolerated (0.5); PolyPhen probably damaging (0.944); catalogued as COSV60095244; called by muse, mutect2, varscan2
- KRTAP24-1 | c.436C>T p.R146C | Missense Mutation (SNP) | VAF 93/1304 reads (7%) | SIFT tolerated (0.2); PolyPhen benign (0); catalogued as rs774705764, COSV61089169, COSV61090157; called by muse, mutect2
- LAIR1 | c.656G>T p.R219M | Missense Mutation (SNP) | VAF 44/574 reads (8%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.917); catalogued as COSV100479840; called by muse, mutect2
- LARP1 | c.2293del p.R765Afs*40 (on ENST00000518297 / NM_033551.3; = p.R688Afs*40 on NM_015315.5 and 6 other RefSeq transcripts) | Frame Shift Del (DEL) | VAF 332/941 reads (35%) | catalogued as COSV60424533; called by mutect2, varscan2
- LATS2 | c.1004G>A p.S335N | Missense Mutation (SNP) | VAF 115/262 reads (44%) | SIFT tolerated (0.19); PolyPhen benign (0.014); catalogued as COSV101231556; called by muse, mutect2, varscan2
- LCOR | c.1036G>A p.A346T | Missense Mutation (SNP) | VAF 72/886 reads (8%) | SIFT deleterious (0.03); PolyPhen benign (0.233); catalogued as rs1387082414; called by muse, mutect2
- LCT | c.1597C>T p.R533C | Missense Mutation (SNP) | VAF 118/289 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs1447178344, COSV104384170, COSV99928573; called by muse, mutect2, varscan2
- LEPR | c.2897A>T p.E966V | Missense Mutation (SNP) | VAF 352/943 reads (37%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.719); catalogued as rs1557709979; called by muse, mutect2, varscan2
- LGALS8 | c.53C>T p.P18L | Missense Mutation (SNP) | VAF 36/834 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1194836311; called by muse, mutect2
- LHFPL3 | c.434del p.F145Sfs*10 | Frame Shift Del (DEL) | VAF 174/472 reads (37%) | catalogued as COSV67821410; called by mutect2, varscan2
- LHX9 | c.735T>A p.G245= | Splice Region (SNP) | VAF 179/383 reads (47%) | catalogued as COSV61330359; called by muse, mutect2, varscan2
- LIG1 | c.356C>T p.P119L | Missense Mutation (SNP) | VAF 199/498 reads (40%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.716); catalogued as rs12981963, COSV54393231; called by muse, mutect2, varscan2
- LILRB4 | c.849G>A p.W283* | Nonsense Mutation (SNP) | VAF 174/433 reads (40%) | catalogued as rs1173438973; called by muse, mutect2, varscan2
- LIMA1 | c.716G>A p.G239D | Missense Mutation (SNP) | VAF 34/480 reads (7%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.689); catalogued as rs1361564936; called by muse, mutect2
- LINGO2 | c.893G>A p.R298H | Missense Mutation (SNP) | VAF 60/659 reads (9%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.874); catalogued as rs867220973, COSV58058236; called by muse, mutect2
- LLGL1 | c.2893C>T p.R965* | Nonsense Mutation (SNP) | VAF 34/354 reads (10%) | catalogued as rs537626619, COSV57496713; called by muse, mutect2
- LRATD1 | c.475G>T p.G159C | Missense Mutation (SNP) | VAF 32/560 reads (6%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.995); catalogued as COSV99707159; called by muse, mutect2
- LRCH3 | c.2117C>T p.P706L | Missense Mutation (SNP) | VAF 374/982 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58388454; called by muse, mutect2, varscan2
- LRP1 | c.5321G>A p.S1774N | Missense Mutation (SNP) | VAF 26/812 reads (3%) | SIFT tolerated (0.09); PolyPhen benign (0.056); catalogued as rs1192420651, COSV54515002; called by muse, mutect2
- LRP4 | c.4013G>T p.G1338V | Missense Mutation (SNP) | VAF 257/720 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV101066892; called by muse, mutect2, varscan2
- LRRC18 | c.425C>T p.A142V | Missense Mutation (SNP) | VAF 183/530 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.617); catalogued as rs763695309; called by muse, mutect2, varscan2
- LRRC27 | c.86C>T p.A29V | Missense Mutation (SNP) | VAF 54/818 reads (7%) | SIFT deleterious (0.02); PolyPhen benign (0.003); catalogued as COSV59812287; called by muse, mutect2
- LRRC37A2 | c.2353C>T p.R785* | Nonsense Mutation (SNP) | VAF 64/3100 reads (2%) | catalogued as rs1433418853; called by muse, mutect2
- LRRC40 | c.601C>T p.R201* | Nonsense Mutation (SNP) | VAF 274/844 reads (32%) | catalogued as rs779018116, COSV63942005; called by muse, mutect2, varscan2
- LRRC4C | c.823G>A p.A275T | Missense Mutation (SNP) | VAF 302/749 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.816); catalogued as rs1167879704; called by muse, mutect2, varscan2
- LRRC56 | c.905del p.G302Afs*108 | Frame Shift Del (DEL) | VAF 171/440 reads (39%) | catalogued as rs1278005871; called by mutect2, varscan2
- LTBP1 | c.514C>T p.R172W | Missense Mutation (SNP) | VAF 149/429 reads (35%) | SIFT deleterious (0); PolyPhen benign (0.226); catalogued as rs779332816, COSV100617225; called by muse, mutect2, varscan2
- LTBP2 | c.2303C>T p.A768V | Missense Mutation (SNP) | VAF 26/526 reads (5%) | SIFT tolerated (0.13); PolyPhen benign (0.006); catalogued as COSV100000402; called by muse, mutect2
- LY9 | c.1540G>T p.G514* | Nonsense Mutation (SNP) | VAF 207/510 reads (41%) | catalogued as COSV54433550; called by muse, mutect2, varscan2
- LYRM2 | c.229G>A p.G77S | Missense Mutation (SNP) | VAF 271/654 reads (41%) | SIFT tolerated, low confidence (0.68); catalogued as rs368296229; called by muse, mutect2, varscan2
- LYST | c.7303G>T p.E2435* | Nonsense Mutation (SNP) | VAF 279/774 reads (36%) | catalogued as COSV67709455; called by muse, mutect2, varscan2
- LYST | c.653C>T p.A218V | Missense Mutation (SNP) | VAF 423/1065 reads (40%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0); catalogued as COSV67703322; called by muse, mutect2, varscan2
- LYST | c.136C>A p.L46I | Missense Mutation (SNP) | VAF 61/1130 reads (5%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); catalogued as COSV67709182; called by muse, mutect2
- LYZL2 | c.424G>A p.V142I (on ENST00000375318; = p.V96I on NM_183058.3) | Missense Mutation (SNP) | VAF 577/1421 reads (41%) | SIFT tolerated (1); PolyPhen benign (0.163); catalogued as rs758022641, COSV100940658; called by muse, mutect2, varscan2
- LZTS2 | c.469G>T p.G157W | Missense Mutation (SNP) | VAF 390/845 reads (46%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.926); catalogued as COSV100932116; called by muse, mutect2, varscan2
- MACC1 | c.2473T>C p.W825R | Missense Mutation (SNP) | VAF 433/1093 reads (40%) | SIFT deleterious (0.01); PolyPhen benign (0.088); catalogued as rs1380608946; called by muse, mutect2, varscan2
- MAEL | c.752G>T p.G251V | Missense Mutation (SNP) | VAF 326/747 reads (44%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.832); catalogued as rs757184732; called by mutect2, varscan2
- MAP3K21 | c.1945C>A p.L649I | Missense Mutation (SNP) | VAF 224/702 reads (32%) | SIFT tolerated (0.39); PolyPhen benign (0.096); catalogued as COSV100786059; called by muse, mutect2, varscan2
- MAP4K5 | c.1040C>A p.P347H | Missense Mutation (SNP) | VAF 182/491 reads (37%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV50160625; called by mutect2, varscan2
- MAP7D2 | c.*26G>T | Splice Region (SNP) | VAF 53/138 reads (38%) | catalogued as COSV101107157; called by muse, mutect2, varscan2
- MAPKBP1 | c.1999-1G>T p.X667_splice (on ENST00000456763 / NM_001128608.2; = p.X661_splice on NM_014994.3) | Splice Site (SNP) | VAF 337/830 reads (41%) | catalogued as COSV99529440; called by muse, mutect2, varscan2
- MARCHF11 | c.587A>G p.H196R | Missense Mutation (SNP) | VAF 283/747 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV60127307; called by muse, mutect2, varscan2
- MAST1 | c.2573G>A p.R858H | Missense Mutation (SNP) | VAF 142/398 reads (36%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.093); catalogued as rs767041987; called by muse, varscan2
- MBD1 | c.549G>T p.Q183H | Missense Mutation (SNP) | VAF 91/705 reads (13%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.748); catalogued as COSV99495851; called by muse, mutect2, varscan2
- MCM3AP | c.1342G>A p.D448N | Missense Mutation (SNP) | VAF 305/692 reads (44%) | SIFT tolerated (0.23); PolyPhen benign (0.001); catalogued as rs777553365; called by muse, mutect2, varscan2
- MEDAG | c.622T>G p.F208V | Missense Mutation (SNP) | VAF 341/837 reads (41%) | SIFT deleterious (0.01); PolyPhen benign (0.164); catalogued as rs1186357568; called by muse, mutect2, varscan2
- MEIOB | c.323C>T p.A108V | Missense Mutation (SNP) | VAF 128/386 reads (33%) | SIFT tolerated (0.72); PolyPhen benign (0.003); catalogued as rs188713181; called by muse, varscan2
- MEP1A | c.1370C>T p.P457L | Missense Mutation (SNP) | VAF 355/919 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.801); catalogued as rs1183429804; called by muse, mutect2, varscan2
- MEP1A | c.1666G>T p.D556Y | Missense Mutation (SNP) | VAF 292/774 reads (38%) | SIFT deleterious (0.03); PolyPhen benign (0.413); catalogued as COSV57919954; called by muse, mutect2, varscan2
- MEP1B | c.1277G>A p.R426Q | Missense Mutation (SNP) | VAF 114/634 reads (18%) | SIFT tolerated (0.8); PolyPhen benign (0.019); catalogued as rs750188910; called by muse, mutect2, varscan2
- METTL17 | c.249G>T p.M83I | Missense Mutation (SNP) | VAF 47/730 reads (6%) | SIFT tolerated (0.37); PolyPhen benign (0); catalogued as COSV100228216; called by muse, mutect2
- MFSD2B | c.1052G>A p.G351E | Missense Mutation (SNP) | VAF 187/536 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.927); catalogued as rs1044788904; called by muse, mutect2, varscan2
- MGA | c.2134G>T p.E712* | Nonsense Mutation (SNP) | VAF 244/702 reads (35%) | catalogued as COSV54958630, COSV99581827; called by muse, mutect2
- MIA3 | c.4608-1G>T p.X1536_splice | Splice Site (SNP) | VAF 372/1053 reads (35%) | catalogued as COSV100485286; called by muse, mutect2, varscan2
- MIEF1 | c.557T>C p.L186S | Missense Mutation (SNP) | VAF 76/898 reads (8%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.986); catalogued as rs1474161533; called by muse, mutect2
- MINK1 | c.1661C>A p.A554D | Missense Mutation (SNP) | VAF 24/412 reads (6%) | SIFT tolerated (0.62); PolyPhen benign (0); catalogued as COSV61791575; called by muse, mutect2
- MITF | c.47dup p.S17Lfs*4 | Frame Shift Ins (INS) | VAF 342/971 reads (35%) | catalogued as rs781679550; called by mutect2, varscan2
- MLXIPL | c.1091G>T p.G364V | Missense Mutation (SNP) | VAF 164/491 reads (33%) | SIFT deleterious (0.03); PolyPhen benign (0.001); catalogued as rs868924782; called by muse, mutect2, varscan2
- MMP20 | c.968G>A p.R323Q | Missense Mutation (SNP) | VAF 266/716 reads (37%) | SIFT deleterious (0.01); PolyPhen benign (0.129); catalogued as rs147615125; called by muse, varscan2
- MORC2 | c.1949C>T p.T650I (on ENST00000397641 / NM_001303256.3; = p.T588I on NM_014941.3) | Missense Mutation (SNP) | VAF 265/677 reads (39%) | SIFT tolerated (0.48); PolyPhen benign (0); catalogued as rs371710965; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- MPDZ | c.4034C>T p.T1345I | Missense Mutation (SNP) | VAF 219/926 reads (24%) | SIFT tolerated (0.06); PolyPhen benign (0); catalogued as rs887936874; called by muse, mutect2, varscan2
- MPHOSPH8 | c.1438G>A p.D480N | Missense Mutation (SNP) | VAF 101/1479 reads (7%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.115); catalogued as rs760788220; called by muse, mutect2
- MPL | c.1327G>T p.G443W | Missense Mutation (SNP) | VAF 202/572 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); catalogued as CM076311; called by muse, mutect2, varscan2
- MRPL1 | c.883C>A p.L295I | Missense Mutation (SNP) | VAF 300/780 reads (38%) | SIFT tolerated (0.93); PolyPhen benign (0.083); catalogued as COSV59674311; called by muse, mutect2, varscan2
- MRPL24 | c.436G>A p.V146I | Missense Mutation (SNP) | VAF 72/1170 reads (6%) | SIFT tolerated (0.05); PolyPhen benign (0.024); catalogued as rs944034695; called by muse, mutect2
- MRS2 | c.779A>G p.D260G | Missense Mutation (SNP) | VAF 34/847 reads (4%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.817); catalogued as rs1314086502; called by muse, mutect2
- MRTFA | c.2188C>T p.P730S | Missense Mutation (SNP) | VAF 104/227 reads (46%) | SIFT tolerated (0.09); PolyPhen benign (0.049); catalogued as rs368896220; called by muse, varscan2
- MRTFA | c.2132C>A p.P711H | Missense Mutation (SNP) | VAF 188/530 reads (35%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.89); catalogued as COSV62936903; called by muse, varscan2
- MSGN1 | c.237C>A p.S79R | Missense Mutation (SNP) | VAF 189/473 reads (40%) | SIFT tolerated (0.13); PolyPhen benign (0.131); catalogued as rs772398177; called by muse, mutect2, varscan2
- MSI2 | c.908G>T p.S303I | Missense Mutation (SNP) | VAF 305/778 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV52355490; called by muse, mutect2, varscan2
- MSN | c.655G>A p.G219R | Missense Mutation (SNP) | VAF 305/368 reads (83%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV64303441; called by muse, mutect2, varscan2
- MTCL1 | c.4960C>T p.R1654C (on ENST00000306329 / NM_001378206.1; = p.R1335C on NM_015210.4) | Missense Mutation (SNP) | VAF 41/177 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs763181044, COSV60412669; called by muse, mutect2, varscan2
- MTF1 | c.854G>A p.G285D | Missense Mutation (SNP) | VAF 170/453 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1327610668; called by muse, mutect2, varscan2
- MTNR1B | c.115G>A p.V39M | Missense Mutation (SNP) | VAF 127/317 reads (40%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.753); catalogued as COSV99925391; called by muse, mutect2, varscan2
- MUC16 | c.28748C>A p.P9583H | Missense Mutation (SNP) | VAF 25/551 reads (5%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.805); catalogued as COSV67479697; called by muse, mutect2
- MUC5B | c.8552C>A p.S2851* | Nonsense Mutation (SNP) | VAF 153/182 reads (84%) | catalogued as COSV71590090; called by muse, varscan2
- MUTYH | c.1489C>A p.Q497K | Missense Mutation (SNP) | VAF 156/450 reads (35%) | SIFT tolerated (0.25); PolyPhen benign (0); catalogued as COSV58344480; called by muse, mutect2, varscan2
- MX2 | c.1795C>T p.P599S | Missense Mutation (SNP) | VAF 229/618 reads (37%) | SIFT tolerated (0.47); PolyPhen benign (0.021); catalogued as rs369062863; called by muse, mutect2, varscan2
- MYEF2 | c.998G>T p.G333V | Missense Mutation (SNP) | VAF 191/514 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99981440; called by muse, mutect2, varscan2
- MYH11 | c.3227C>T p.A1076V | Missense Mutation (SNP) | VAF 256/638 reads (40%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.523); catalogued as rs371205331; ClinVar: uncertain significance; called by muse, varscan2
- MYH11 | c.530+2T>C p.X177_splice | Splice Site (SNP) | VAF 112/1058 reads (11%) | catalogued as rs779086212; called by muse, mutect2
- MYH2 | c.5254C>A p.Q1752K | Missense Mutation (SNP) | VAF 99/1377 reads (7%) | SIFT deleterious (0.03); PolyPhen benign (0.042); catalogued as COSV55443944; called by muse, mutect2
- MYH2 | c.3745-1G>A p.X1249_splice | Splice Site (SNP) | VAF 124/315 reads (39%) | catalogued as COSV55436260; called by muse, mutect2, varscan2
- MYH4 | c.3535C>T p.R1179C | Missense Mutation (SNP) | VAF 383/1078 reads (36%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.997); catalogued as rs757546892; called by muse, mutect2, varscan2
- MYH6 | c.4141G>A p.A1381T | Missense Mutation (SNP) | VAF 362/1006 reads (36%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.955); catalogued as rs753774406, COSV100676630; ClinVar: uncertain significance; called by muse, varscan2
- MYO18A | c.2408G>A p.R803H | Missense Mutation (SNP) | VAF 272/736 reads (37%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.742); catalogued as rs774435895; called by muse, mutect2, varscan2
- MYO18B | c.1963A>C p.S655R | Missense Mutation (SNP) | VAF 303/704 reads (43%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.792); catalogued as COSV59137490; called by muse, mutect2, varscan2
- MYO1H | c.1729G>T p.G577W | Missense Mutation (SNP) | VAF 88/223 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1444768284; called by muse, mutect2, varscan2
- MYO1H | c.2183G>A p.R728K | Missense Mutation (SNP) | VAF 40/773 reads (5%) | SIFT tolerated (0.79); PolyPhen benign (0.015); catalogued as rs1278662272, COSV100183159; called by muse, mutect2
- MYO5A | c.3982G>A p.E1328K | Missense Mutation (SNP) | VAF 423/1105 reads (38%) | SIFT tolerated (0.83); PolyPhen benign (0); catalogued as COSV62559027; called by muse, mutect2, varscan2
- MYO9B | c.412C>T p.R138C | Missense Mutation (SNP) | VAF 169/425 reads (40%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs1432294489; called by muse, mutect2, varscan2
- MYOM3 | c.4145G>A p.R1382H | Missense Mutation (SNP) | VAF 208/515 reads (40%) | SIFT tolerated (0.32); PolyPhen benign (0.003); catalogued as rs574626787; called by muse, mutect2, varscan2
- NAALAD2 | c.640G>T p.G214* | Nonsense Mutation (SNP) | VAF 286/1052 reads (27%) | catalogued as COSV100428860; called by muse, mutect2, varscan2
- NALCN | c.1048-1G>T p.X350_splice | Splice Site (SNP) | VAF 224/810 reads (28%) | catalogued as rs1269008796; called by mutect2, varscan2
- NBAS | c.6833T>C p.V2278A | Missense Mutation (SNP) | VAF 196/552 reads (36%) | SIFT tolerated (0.1); PolyPhen benign (0.054); catalogued as COSV99867070; called by muse, varscan2
- NBEA | c.3974G>A p.R1325Q | Missense Mutation (SNP) | VAF 378/910 reads (42%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.968); catalogued as rs1165053722, COSV59813225; called by muse, mutect2, varscan2
- NCKAP5 | c.5050-1G>T p.X1684_splice | Splice Site (SNP) | VAF 295/794 reads (37%) | catalogued as rs1332894004; called by muse, mutect2, varscan2
- NCKAP5 | c.2419G>A p.G807S | Missense Mutation (SNP) | VAF 85/740 reads (11%) | SIFT tolerated (0.08); PolyPhen benign (0.116); catalogued as COSV58446248; called by muse, mutect2, varscan2
- NEFH | c.2584G>T p.E862* | Nonsense Mutation (SNP) | VAF 296/663 reads (45%) | catalogued as rs866365871; called by muse, mutect2, varscan2
- NEURL4 | c.332C>T p.P111L | Missense Mutation (SNP) | VAF 52/829 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59760990; called by muse, mutect2
- NF1 | c.5548G>A p.V1850I (on ENST00000358273 / NM_001042492.3; = p.V1829I on NM_000267.3) | Missense Mutation (SNP) | VAF 82/1102 reads (7%) | SIFT deleterious (0); PolyPhen benign (0.437); catalogued as COSV100648645, COSV62214296; called by muse, mutect2
- NFASC | c.224G>A p.W75* (on ENST00000339876 / NM_001378329.1; = p.W69* on NM_015090.4 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 220/528 reads (42%) | catalogued as COSV58371328; called by muse, mutect2, varscan2
- NFAT5 | c.126A>C p.E42D | Missense Mutation (SNP) | VAF 422/1064 reads (40%) | SIFT deleterious (0.01); PolyPhen benign (0.351); catalogued as rs895591027; called by muse, mutect2, varscan2
- NFE2 | c.1052C>A p.A351E | Missense Mutation (SNP) | VAF 74/528 reads (14%) | SIFT deleterious (0.04); PolyPhen benign (0.192); catalogued as COSV56455186; called by muse, mutect2, varscan2
- NFIA | c.448C>A p.L150I | Missense Mutation (SNP) | VAF 258/640 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV64537004; called by muse, mutect2, varscan2
- NFKBIE | c.1437+1G>T p.X479_splice (on ENST00000275015; = p.X340_splice on NM_004556.3) | Splice Site (SNP) | VAF 72/513 reads (14%) | catalogued as COSV51489469; called by muse, mutect2, varscan2
- NFX1 | c.166C>A p.L56I | Missense Mutation (SNP) | VAF 49/1080 reads (5%) | SIFT tolerated, low confidence (0.38); PolyPhen benign (0.185); catalogued as rs1363174726; called by muse, mutect2
- NGDN | c.16G>A p.V6M | Missense Mutation (SNP) | VAF 154/407 reads (38%) | SIFT tolerated (0.05); PolyPhen benign (0.006); catalogued as rs1442304703; called by muse, mutect2, varscan2
- NHSL1 | c.1288G>A p.A430T | Missense Mutation (SNP) | VAF 52/798 reads (7%) | SIFT tolerated (0.19); PolyPhen benign (0.085); catalogued as rs77193799, COSV104413971; called by muse, mutect2
- NID1 | c.1193C>T p.S398L | Missense Mutation (SNP) | VAF 36/919 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); catalogued as rs1395059767; called by muse, mutect2
- NIM1K | c.1153G>T p.G385W | Missense Mutation (SNP) | VAF 54/752 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58140589; called by muse, mutect2
- NIPA2 | c.98del p.K33Rfs*12 | Frame Shift Del (DEL) | VAF 252/681 reads (37%) | catalogued as rs145147241; called by mutect2, varscan2
- NIPAL1 | c.1000G>T p.A334S | Missense Mutation (SNP) | VAF 293/701 reads (42%) | SIFT tolerated (0.07); PolyPhen benign (0.098); catalogued as COSV55006628; called by muse, mutect2, varscan2
- NIPBL | c.5356A>C p.I1786L | Missense Mutation (SNP) | VAF 206/530 reads (39%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.778); catalogued as COSV56950250; called by muse, mutect2, varscan2
- NKD2 | c.165G>T p.K55N | Missense Mutation (SNP) | VAF 47/356 reads (13%) | SIFT tolerated (0.08); PolyPhen benign (0.148); catalogued as COSV56889965; called by muse, mutect2, varscan2
- NKX2-2 | c.370del p.D124Tfs*60 | Frame Shift Del (DEL) | VAF 174/412 reads (42%) | catalogued as rs752776917; called by mutect2, varscan2
- NLRC4 | c.419G>A p.W140* | Nonsense Mutation (SNP) | VAF 49/493 reads (10%) | catalogued as rs775526806, COSV100707493; called by muse, mutect2
- NLRP11 | c.95G>T p.R32L | Missense Mutation (SNP) | VAF 224/622 reads (36%) | SIFT deleterious (0.04); PolyPhen benign (0.195); catalogued as rs749940136, COSV64087300; called by muse, mutect2, varscan2
- NLRP13 | c.2261G>T p.R754I | Missense Mutation (SNP) | VAF 67/803 reads (8%) | SIFT deleterious (0.01); PolyPhen benign (0.042); catalogued as COSV61621676; called by muse, mutect2
- NLRP2 | c.476G>T p.R159M | Missense Mutation (SNP) | VAF 110/656 reads (17%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.659); catalogued as COSV54761230; called by muse, mutect2, varscan2
- NOTCH1 | c.6535C>T p.R2179W | Missense Mutation (SNP) | VAF 117/271 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.895); catalogued as rs768400804; called by muse, mutect2, varscan2
- NOTCH1 | c.6180+1G>A p.X2060_splice | Splice Site (SNP) | VAF 53/537 reads (10%) | catalogued as COSV53055461, COSV99488237; called by muse, mutect2
- NOTCH1 | c.3644-1G>T p.X1215_splice | Splice Site (SNP) | VAF 16/266 reads (6%) | catalogued as COSV53089596; called by muse, mutect2
- NOTCH1 | c.1247G>A p.C416Y | Missense Mutation (SNP) | VAF 39/662 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53028453, COSV53035640; called by muse, mutect2
- NOTCH4 | c.1679G>A p.C560Y | Missense Mutation (SNP) | VAF 50/964 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV66682065; called by muse, mutect2
- NPAT | c.3117dup p.S1040Ifs*18 | Frame Shift Ins (INS) | VAF 199/774 reads (26%) | catalogued as rs1565305809; called by mutect2, varscan2
- NPNT | c.887C>A p.P296H | Missense Mutation (SNP) | VAF 324/773 reads (42%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as COSV59757918; called by muse, mutect2, varscan2
- NPR2 | c.2923C>T p.P975S | Missense Mutation (SNP) | VAF 30/674 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52413751; called by muse, mutect2
- NR3C2 | c.2119G>T p.G707W | Missense Mutation (SNP) | VAF 14/430 reads (3%) | SIFT deleterious (0); PolyPhen possibly damaging (0.662); catalogued as COSV60998089; called by muse, mutect2
- NRK | c.1009A>G p.R337G | Missense Mutation (SNP) | VAF 30/554 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.906); catalogued as COSV54591259; called by muse, mutect2
- NRROS | c.130C>T p.R44* | Nonsense Mutation (SNP) | VAF 97/250 reads (39%) | catalogued as rs556333034; called by muse, mutect2, varscan2
- NRXN1 | c.494C>A p.A165E | Missense Mutation (SNP) | VAF 60/706 reads (8%) | SIFT tolerated (0.2); PolyPhen benign (0.116); catalogued as COSV101277659, COSV68003819; called by muse, mutect2
- NRXN2 | c.4966G>A p.A1656T | Missense Mutation (SNP) | VAF 89/188 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as rs758684664, COSV55457456; called by muse, mutect2, varscan2
- NRXN3 | c.1076dup p.T360Yfs*10 | Frame Shift Ins (INS) | VAF 150/649 reads (23%) | catalogued as rs1298969589; called by mutect2, varscan2
- NUP188 | c.776A>G p.D259G | Missense Mutation (SNP) | VAF 26/815 reads (3%) | SIFT deleterious (0.02); PolyPhen benign (0.055); catalogued as COSV65361027; called by muse, mutect2
- NUTM2F | c.319del p.L107Sfs*145 | Frame Shift Del (DEL) | VAF 19/133 reads (14%) | catalogued as rs1194290563; called by mutect2, varscan2
- OBSCN | c.7901T>C p.V2634A | Missense Mutation (SNP) | VAF 48/406 reads (12%) | SIFT tolerated (0.76); PolyPhen possibly damaging (0.846); catalogued as COSV52747535; called by muse, mutect2, varscan2
- OBSCN | c.20977del p.A6993Pfs*79 | Frame Shift Del (DEL) | VAF 102/260 reads (39%) | catalogued as rs762005098; called by mutect2, varscan2
- OBSL1 | c.3125C>T p.P1042L | Missense Mutation (SNP) | VAF 118/322 reads (37%) | SIFT tolerated (0.15); PolyPhen benign (0.019); catalogued as rs368412979; called by muse, mutect2, varscan2
- OGDHL | c.2590+1G>A p.X864_splice | Splice Site (SNP) | VAF 189/511 reads (37%) | catalogued as COSV100934406; called by muse, mutect2, varscan2
- OGG1 | c.1036G>T p.G346W | Missense Mutation (SNP) | VAF 26/589 reads (4%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.02); catalogued as COSV56538163; called by muse, mutect2
- OLFM2 | c.79C>A p.P27T | Missense Mutation (SNP) | VAF 65/704 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.938); catalogued as COSV53428656; called by muse, mutect2
- OLFML2A | c.1898G>A p.R633Q | Missense Mutation (SNP) | VAF 57/536 reads (11%) | SIFT deleterious (0.01); PolyPhen benign (0.158); catalogued as rs377560457; called by muse, mutect2, varscan2
- OR10X1 | c.154C>A p.L52I | Missense Mutation (SNP) | VAF 38/822 reads (5%) | SIFT tolerated (0.18); PolyPhen benign (0.005); catalogued as COSV100936640; called by muse, mutect2
- OR10Z1 | c.775T>C p.Y259H | Missense Mutation (SNP) | VAF 31/368 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as rs1332311828; called by muse, mutect2
- OR11H12 | c.26C>A p.T9N | Missense Mutation (SNP) | VAF 123/680 reads (18%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0); catalogued as COSV73543879; called by muse, mutect2, varscan2
- OR11H4 | c.352G>T p.G118* | Nonsense Mutation (SNP) | VAF 150/360 reads (42%) | catalogued as COSV59559896; called by muse, mutect2, varscan2
- OR2L2 | c.512G>T p.R171I | Missense Mutation (SNP) | VAF 371/949 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.619); catalogued as COSV63560714; called by muse, mutect2, varscan2
- OR2M7 | c.674T>A p.V225D | Missense Mutation (SNP) | VAF 599/1532 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV100522411; called by muse, mutect2, varscan2
- OR2T3 | c.938G>T p.R313I | Missense Mutation (SNP) | VAF 414/2174 reads (19%) | SIFT tolerated (0.4); PolyPhen benign (0.352); catalogued as COSV100613318, COSV62082892; called by muse, mutect2, varscan2
- OR2V2 | c.851C>T p.P284L | Missense Mutation (SNP) | VAF 47/567 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV60316680; called by muse, mutect2
- OR4C11 | c.928G>T p.G310* | Nonsense Mutation (SNP) | VAF 163/395 reads (41%) | catalogued as rs772341211, COSV56354418; called by muse, mutect2, varscan2
- OR4K14 | c.187C>A p.L63M | Missense Mutation (SNP) | VAF 191/521 reads (37%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.801); catalogued as COSV59292604; called by muse, mutect2, varscan2
- OR4K3 | c.512C>A p.P171H | Missense Mutation (SNP) | VAF 297/731 reads (41%) | SIFT deleterious, low confidence (0.03); PolyPhen probably damaging (0.984); catalogued as rs893212398; called by muse, mutect2, varscan2
- OR51B5 | c.528C>A p.F176L | Missense Mutation (SNP) | VAF 69/531 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56177121; called by muse, mutect2, varscan2
- OR51Q1 | c.193C>A p.L65I | Missense Mutation (SNP) | VAF 46/499 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV56180306; called by muse, mutect2
- OR52E4 | c.710A>C p.K237T | Missense Mutation (SNP) | VAF 360/871 reads (41%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.896); catalogued as COSV100389296; called by muse, mutect2, varscan2
- OR52L1 | c.768del p.F256Lfs*57 | Frame Shift Del (DEL) | VAF 209/567 reads (37%) | catalogued as COSV59988592; called by mutect2, varscan2
- OR52N4 | c.162G>T p.E54D | Missense Mutation (SNP) | VAF 361/881 reads (41%) | SIFT tolerated (0.19); PolyPhen benign (0.044); catalogued as COSV57891818; called by muse, mutect2, varscan2
- OR56A5 | c.256G>A p.A86T | Missense Mutation (SNP) | VAF 107/1782 reads (6%) | SIFT deleterious (0.04); PolyPhen benign (0.317); catalogued as COSV60827062; called by muse, mutect2
- OR5A1 | c.948G>T p.*316Yext*? | Nonstop Mutation (SNP) | VAF 52/313 reads (17%) | catalogued as COSV100118269; called by muse, mutect2, varscan2
- OR5AR1 | c.24G>T p.M8I | Missense Mutation (SNP) | VAF 17/383 reads (4%) | SIFT tolerated (0.3); PolyPhen benign (0); catalogued as COSV57252955; called by muse, mutect2
- OR5R1 | c.859C>T p.P287S | Missense Mutation (SNP) | VAF 382/1083 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs763424734; called by muse, mutect2
- OR8D1 | c.277C>A p.L93I | Missense Mutation (SNP) | VAF 185/545 reads (34%) | SIFT deleterious (0); PolyPhen benign (0.027); catalogued as COSV100766485, COSV63441685; called by muse, mutect2, varscan2
- OR8I2 | c.905G>T p.R302I | Missense Mutation (SNP) | VAF 122/385 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.451); catalogued as COSV56167392; called by muse, mutect2, varscan2
- OR8S1 | c.299A>G p.Q100R | Missense Mutation (SNP) | VAF 326/849 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1044784057; called by muse, mutect2, varscan2
- OS9 | c.480G>T p.K160N | Missense Mutation (SNP) | VAF 227/614 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99232682; called by muse, mutect2, varscan2
- PABPC3 | c.1502G>A p.R501H | Missense Mutation (SNP) | VAF 54/628 reads (9%) | SIFT tolerated (0.19); PolyPhen benign (0); catalogued as rs769964946; called by muse, mutect2
- PAF1 | c.1379C>A p.S460Y | Missense Mutation (SNP) | VAF 35/269 reads (13%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.462); catalogued as COSV99655582; called by muse, mutect2, varscan2
- PAIP2B | c.107G>T p.W36L | Missense Mutation (SNP) | VAF 86/1064 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV99731756; called by muse, mutect2
- PAK1 | c.1351G>T p.G451C | Missense Mutation (SNP) | VAF 36/765 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53696107; called by muse, mutect2
- PAPLN | c.1288G>T p.E430* (on ENST00000554301; = p.E403* on NM_173462.4) | Nonsense Mutation (SNP) | VAF 30/439 reads (7%) | catalogued as rs1330672357; called by muse, mutect2
- PAPPA2 | c.1267C>A p.L423M | Missense Mutation (SNP) | VAF 110/1512 reads (7%) | SIFT tolerated (0.15); PolyPhen benign (0.292); catalogued as COSV62776856, COSV62786106; called by muse, mutect2
- PARP8 | c.884del p.P295Lfs*10 | Frame Shift Del (DEL) | VAF 158/416 reads (38%) | catalogued as COSV55859465; called by mutect2, varscan2
- PARP8 | c.1624G>T p.G542* | Nonsense Mutation (SNP) | VAF 294/782 reads (38%) | catalogued as rs774691301; called by mutect2, varscan2
- PATJ | c.4518G>T p.R1506S | Missense Mutation (SNP) | VAF 54/780 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs867970683; called by muse, mutect2
- PATL2 | c.1282G>A p.E428K | Missense Mutation (SNP) | VAF 214/588 reads (36%) | SIFT tolerated (0.49); PolyPhen benign (0.027); catalogued as rs760151963, COSV55991236; called by muse, mutect2, varscan2
- PAXBP1 | c.754C>T p.R252C | Missense Mutation (SNP) | VAF 476/1281 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs527335552; called by muse, mutect2, varscan2
- PBX2 | c.217G>A p.A73T | Missense Mutation (SNP) | VAF 244/587 reads (42%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.718); catalogued as rs1400207484, COSV66708646; called by muse, mutect2, varscan2
- PCDH15 | c.3968G>T p.R1323I | Missense Mutation (SNP) | VAF 304/794 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); catalogued as COSV57280448, COSV57285586; called by muse, mutect2, varscan2
- PCDHA11 | c.200C>T p.A67V | Missense Mutation (SNP) | VAF 118/279 reads (42%) | SIFT tolerated, low confidence (0.33); PolyPhen benign (0.001); catalogued as rs1403563775; called by muse, mutect2, varscan2
- PCF11 | c.4198C>A p.L1400M | Missense Mutation (SNP) | VAF 249/704 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100018659; called by muse, mutect2, varscan2
- PCIF1 | c.875C>T p.A292V | Missense Mutation (SNP) | VAF 164/357 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.951); catalogued as rs749402768, COSV65026485; called by muse, varscan2
- PCLO | c.6925G>T p.G2309W | Missense Mutation (SNP) | VAF 42/856 reads (5%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.924); catalogued as COSV100440249; called by muse, mutect2
- PCNT | c.4177G>T p.G1393W | Missense Mutation (SNP) | VAF 32/376 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.624); catalogued as rs753662756, COSV100855000; called by muse, mutect2
- PCSK2 | c.478G>T p.G160C | Missense Mutation (SNP) | VAF 36/1050 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs1290255908, COSV52740210; called by muse, mutect2
- PDE6H | c.113C>A p.P38H | Missense Mutation (SNP) | VAF 34/884 reads (4%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.969); catalogued as COSV99844029; called by muse, mutect2
- PDGFRA | c.869G>A p.C290Y | Missense Mutation (SNP) | VAF 332/775 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57276228; called by muse, mutect2, varscan2
- PDGFRA | c.2293C>A p.P765T | Missense Mutation (SNP) | VAF 285/712 reads (40%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.969); catalogued as rs1325295795; called by muse, mutect2, varscan2
- PDIA5 | c.1157dup p.P387Afs*44 | Frame Shift Ins (INS) | VAF 150/580 reads (26%) | catalogued as rs766425459; called by mutect2, varscan2
- PDIK1L | c.500C>A p.P167H | Missense Mutation (SNP) | VAF 48/1170 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV65322345; called by muse, mutect2
- PFAS | c.2793G>T p.Q931H | Missense Mutation (SNP) | VAF 272/654 reads (42%) | SIFT tolerated (0.14); PolyPhen benign (0.174); catalogued as COSV58978681; called by muse, mutect2, varscan2
- PFDN5 | c.455C>T p.A152V | Missense Mutation (SNP) | VAF 51/701 reads (7%) | SIFT deleterious (0.02); PolyPhen benign (0.005); catalogued as COSV54477009; called by muse, mutect2
- PGS1 | c.1448T>G p.L483R | Missense Mutation (SNP) | VAF 202/600 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1179152699; called by muse, mutect2, varscan2
- PHF2 | c.1831G>A p.D611N | Missense Mutation (SNP) | VAF 118/315 reads (37%) | SIFT deleterious (0.04); PolyPhen benign (0.13); catalogued as COSV63683778; called by muse, mutect2, varscan2
- PHTF1 | c.142C>A p.P48T | Missense Mutation (SNP) | VAF 270/752 reads (36%) | SIFT tolerated (0.18); PolyPhen benign (0.044); catalogued as COSV63366818; called by muse, mutect2, varscan2
- PI4K2B | c.1303G>T p.G435W | Missense Mutation (SNP) | VAF 265/733 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV53510259; called by muse, mutect2, varscan2
- PIEZO2 | c.6374A>C p.N2125T | Missense Mutation (SNP) | VAF 372/994 reads (37%) | SIFT tolerated (0.2); PolyPhen benign (0.388); catalogued as COSV53287401; called by muse, mutect2, varscan2
- PIEZO2 | c.3239A>G p.Y1080C | Missense Mutation (SNP) | VAF 257/647 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.87); catalogued as rs1365014954; called by muse, mutect2, varscan2
- PIGK | c.431C>A p.P144H | Missense Mutation (SNP) | VAF 345/1010 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV100769798; called by muse, mutect2, varscan2
- PIGQ | c.266C>T p.P89L | Missense Mutation (SNP) | VAF 22/302 reads (7%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.065); catalogued as COSV50313491; called by muse, mutect2
- PITRM1 | c.2620C>T p.P874S | Missense Mutation (SNP) | VAF 202/489 reads (41%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.831); catalogued as COSV56539652; called by muse, mutect2, varscan2
- PKD1L1 | c.8335G>A p.A2779T | Missense Mutation (SNP) | VAF 24/728 reads (3%) | SIFT tolerated (0.96); PolyPhen benign (0.001); catalogued as COSV51842114; called by muse, mutect2
- PKDREJ | c.1889C>T p.P630L | Missense Mutation (SNP) | VAF 40/685 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.873); catalogued as rs1569005819; called by muse, mutect2
- PLA1A | c.1359A>G p.I453M | Missense Mutation (SNP) | VAF 256/640 reads (40%) | SIFT tolerated (0.09); PolyPhen benign (0.006); catalogued as rs1373275641; called by muse, mutect2, varscan2
- PLAAT5 | c.757G>A p.A253T | Missense Mutation (SNP) | VAF 86/237 reads (36%) | SIFT deleterious (0.03); PolyPhen benign (0.436); catalogued as rs201362246, COSV57136693; called by muse, mutect2, varscan2
- PLB1 | c.556-3C>T | Splice Region (SNP) | VAF 376/1068 reads (35%) | catalogued as rs766498216; called by muse, mutect2, varscan2
- PLBD1 | c.335+1G>A p.X112_splice | Splice Site (SNP) | VAF 141/341 reads (41%) | catalogued as rs781474376; called by muse, mutect2, varscan2
- PLCD4 | c.1273G>A p.E425K | Missense Mutation (SNP) | VAF 240/693 reads (35%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.446); catalogued as rs554285261; called by muse, mutect2, varscan2
- PLCH1 | c.874C>A p.P292T (on ENST00000340059 / NM_001130960.2; = p.P304T on NM_014996.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 38/946 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs1178326338; called by muse, mutect2
- PLCH2 | c.2898del p.G969Dfs*77 | Frame Shift Del (DEL) | VAF 96/224 reads (43%) | catalogued as rs756194318; called by mutect2, varscan2
- PLD3 | c.1223G>A p.R408Q | Missense Mutation (SNP) | VAF 419/1056 reads (40%) | SIFT tolerated (0.43); PolyPhen benign (0.087); catalogued as rs1208349951; called by muse, mutect2, varscan2
- PLEC | c.9765G>T p.Q3255H (on ENST00000322810 / NM_201380.4; = p.Q3145H on NM_000445.5) | Missense Mutation (SNP) | VAF 106/244 reads (43%) | SIFT deleterious (0); PolyPhen benign (0.28); catalogued as rs1554681897; called by muse, mutect2, varscan2
- PLEC | c.7472C>T p.A2491V (on ENST00000322810 / NM_201380.4; = p.A2381V on NM_000445.5) | Missense Mutation (SNP) | VAF 216/526 reads (41%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.052); catalogued as rs370003608; ClinVar: uncertain significance / likely benign; called by muse, mutect2, varscan2
- PLEKHA5 | c.2244G>A p.T748= | Splice Region (SNP) | VAF 176/497 reads (35%) | catalogued as rs1399521340; called by muse, varscan2
- PLEKHG1 | c.3880C>A p.L1294I | Missense Mutation (SNP) | VAF 321/856 reads (38%) | SIFT tolerated, low confidence (0.22); PolyPhen benign (0); catalogued as COSV62051705; called by muse, mutect2, varscan2
- PLEKHG6 | c.1385T>C p.V462A | Missense Mutation (SNP) | VAF 42/430 reads (10%) | SIFT deleterious (0); PolyPhen benign (0.108); catalogued as rs1438656919; called by muse, mutect2, varscan2
- PLEKHH3 | c.355C>T p.R119* | Nonsense Mutation (SNP) | VAF 286/658 reads (43%) | catalogued as COSV99511953; called by muse, mutect2, varscan2
- PNLIP | c.590C>A p.P197H | Missense Mutation (SNP) | VAF 213/583 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs760557233, COSV100981876; called by muse, mutect2, varscan2
- PNMT | c.139C>A p.L47M | Missense Mutation (SNP) | VAF 32/258 reads (12%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.954); catalogued as rs1225426026; called by muse, mutect2, varscan2
- PNPLA6 | c.1368dup p.S457Vfs*15 (on ENST00000414982 / NM_001166111.2; = p.S409Vfs*15 on NM_006702.5) | Frame Shift Ins (INS) | VAF 148/420 reads (35%) | catalogued as rs757691750; called by mutect2, varscan2
- POF1B | c.505del p.T169Qfs*2 | Frame Shift Del (DEL) | VAF 262/324 reads (81%) | catalogued as COSV53138939; called by mutect2, varscan2
- POLG | c.997C>A p.Q333K | Missense Mutation (SNP) | VAF 85/1200 reads (7%) | SIFT tolerated (0.48); PolyPhen benign (0.01); catalogued as COSV51523065; called by muse, mutect2
- POTEA | c.317C>T p.A106V | Missense Mutation (SNP) | VAF 89/936 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.862); catalogued as rs374073241; called by muse, mutect2
- PPFIA2 | c.2643-1G>T p.X881_splice | Splice Site (SNP) | VAF 26/449 reads (6%) | catalogued as COSV61024958; called by muse, mutect2
- PPIAL4A | c.268C>T p.R90* | Nonsense Mutation (SNP) | VAF 129/362 reads (36%) | catalogued as rs1464653634; called by muse, mutect2, varscan2
- PPP1CC | c.748-1G>T p.X250_splice | Splice Site (SNP) | VAF 140/395 reads (35%) | catalogued as COSV100534913; called by muse, mutect2, varscan2
- PPP1R13B | c.1873C>T p.P625S | Missense Mutation (SNP) | VAF 216/535 reads (40%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.878); catalogued as rs754061946, COSV52456099; called by muse, mutect2, varscan2
- PPP1R3E | c.400del p.R134Afs*25 | Frame Shift Del (DEL) | VAF 143/334 reads (43%) | catalogued as rs747803822; called by mutect2, varscan2
- PRAG1 | c.1667C>T p.S556F | Missense Mutation (SNP) | VAF 125/277 reads (45%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); catalogued as rs773878783; called by muse, mutect2, varscan2
- PRDM1 | c.531G>T p.Q177H | Missense Mutation (SNP) | VAF 210/561 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); catalogued as COSV64846405; called by muse, mutect2, varscan2
- PRDM12 | c.983C>T p.T328I | Missense Mutation (SNP) | VAF 69/146 reads (47%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0); catalogued as rs1195182085; called by muse, mutect2
- PRDX6 | c.25G>A p.D9N | Missense Mutation (SNP) | VAF 171/422 reads (41%) | SIFT deleterious (0.04); PolyPhen benign (0.067); catalogued as rs377315650; called by muse, mutect2, varscan2
- PRKAG2 | c.223G>T p.G75W | Missense Mutation (SNP) | VAF 35/675 reads (5%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.818); catalogued as COSV55227476, COSV99835074; called by muse, mutect2
- PRKCA | c.666G>T p.Q222H | Missense Mutation (SNP) | VAF 320/802 reads (40%) | SIFT tolerated (0.13); PolyPhen benign (0); catalogued as rs753286297; called by muse, mutect2, varscan2
- PRKN | c.1283dup p.N428Kfs*141 | Frame Shift Ins (INS) | VAF 212/504 reads (42%) | catalogued as rs758718482; called by mutect2, varscan2
- PRKN | c.925G>T p.E309* | Nonsense Mutation (SNP) | VAF 249/683 reads (36%) | catalogued as rs1168877682; called by muse, mutect2, varscan2
- PRPF38B | c.1016G>A p.R339H | Missense Mutation (SNP) | VAF 437/1215 reads (36%) | SIFT deleterious (0); PolyPhen benign (0.018); catalogued as rs779515848, COSV100898205; called by muse, mutect2, varscan2
- PSMD4 | c.226C>T p.H76Y | Missense Mutation (SNP) | VAF 48/704 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as rs1429534641, COSV64393995, COSV99068722; called by muse, mutect2
- PSMG2 | c.185C>T p.A62V | Missense Mutation (SNP) | VAF 231/594 reads (39%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.593); catalogued as rs751761960; called by muse, mutect2, varscan2
- PTCH2 | c.3258-1G>T p.X1086_splice | Splice Site (SNP) | VAF 78/460 reads (17%) | catalogued as COSV63400429; called by muse, mutect2, varscan2
- PTCH2 | c.2642del p.P881Hfs*112 | Frame Shift Del (DEL) | VAF 30/263 reads (11%) | catalogued as rs1337855606; called by mutect2, varscan2
- PTGS1 | c.148G>A p.G50S | Missense Mutation (SNP) | VAF 49/451 reads (11%) | SIFT tolerated (0.09); PolyPhen benign (0.205); catalogued as rs201276316, COSV99793654; called by muse, mutect2, varscan2
- PTPN18 | c.112G>A p.A38T | Missense Mutation (SNP) | VAF 211/565 reads (37%) | SIFT tolerated (0.19); PolyPhen benign (0.028); catalogued as rs771491113; called by muse, mutect2, varscan2
- PTPRB | c.3478G>T p.E1160* | Nonsense Mutation (SNP) | VAF 76/1258 reads (6%) | catalogued as COSV54252129; called by muse, mutect2
- PTPRB | c.3367G>T p.D1123Y | Missense Mutation (SNP) | VAF 56/910 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV54238260, COSV54248666; called by muse, mutect2
- PTPRD | c.3913C>A p.P1305T | Missense Mutation (SNP) | VAF 212/606 reads (35%) | SIFT tolerated (0.39); PolyPhen benign (0.003); catalogued as rs917532047; called by mutect2, varscan2
- PTPRU | c.1157C>T p.A386V | Missense Mutation (SNP) | VAF 163/347 reads (47%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.958); catalogued as rs1557437634; called by muse, mutect2, varscan2
- PTTG1IP | c.377G>A p.S126N | Missense Mutation (SNP) | VAF 40/760 reads (5%) | SIFT tolerated (0.34); PolyPhen probably damaging (0.937); catalogued as rs1413553607; called by muse, mutect2
- PUS7L | c.1203dup p.Q402Tfs*4 | Frame Shift Ins (INS) | VAF 258/674 reads (38%) | catalogued as rs1361634403; called by mutect2, varscan2
- QTRT1 | c.861+2T>C p.X287_splice | Splice Site (SNP) | VAF 48/368 reads (13%) | catalogued as rs772314158; called by muse, mutect2, varscan2
- R3HDM2 | c.2259G>T p.Q753H | Missense Mutation (SNP) | VAF 122/334 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as rs771972098; called by muse, mutect2, varscan2
- RAB39B | c.463C>T p.R155* | Nonsense Mutation (SNP) | VAF 338/432 reads (78%) | catalogued as COSV101034956, COSV65624331; called by muse, mutect2, varscan2
- RAB3GAP1 | c.1174C>T p.R392* | Nonsense Mutation (SNP) | VAF 322/917 reads (35%) | catalogued as rs779312077, CM050772; called by muse, mutect2, varscan2
- RADIL | c.2243G>T p.S748I | Missense Mutation (SNP) | VAF 201/496 reads (41%) | SIFT deleterious (0.03); PolyPhen benign (0.205); catalogued as rs376135961; called by muse, mutect2, varscan2
- RADIL | c.1000C>T p.H334Y | Missense Mutation (SNP) | VAF 22/582 reads (4%) | SIFT deleterious (0.02); PolyPhen benign (0); catalogued as COSV101271295; called by muse, mutect2
- RAI1 | c.3200G>A p.R1067H | Missense Mutation (SNP) | VAF 146/366 reads (40%) | SIFT deleterious (0); PolyPhen benign (0.387); catalogued as COSV99884094; called by muse, mutect2, varscan2
- RAPGEFL1 | c.1712C>A p.P571H | Missense Mutation (SNP) | VAF 32/778 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52864970; called by muse, mutect2
- RASA2 | c.685-1G>T p.X229_splice | Splice Site (SNP) | VAF 33/311 reads (11%) | catalogued as rs778990407, COSV99656723; called by muse, mutect2, varscan2
- RASD1 | c.715C>T p.P239S | Missense Mutation (SNP) | VAF 191/436 reads (44%) | SIFT tolerated (0.74); PolyPhen benign (0); catalogued as rs780215994; called by muse, mutect2, varscan2
- RASIP1 | c.899C>A p.P300H | Missense Mutation (SNP) | VAF 27/672 reads (4%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.737); catalogued as COSV55805951; called by muse, mutect2
- RASL11B | c.356C>T p.S119F | Missense Mutation (SNP) | VAF 68/1076 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs755604054; called by muse, mutect2
- RASSF5 | c.223del p.R75Gfs*91 | Frame Shift Del (DEL) | VAF 114/278 reads (41%) | catalogued as rs1553394030; called by mutect2, varscan2
- RBM12 | c.4G>T p.A2S | Missense Mutation (SNP) | VAF 440/1075 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV58289610; called by muse, mutect2, varscan2
- RBM27 | c.935G>T p.S312I | Missense Mutation (SNP) | VAF 56/724 reads (8%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.557); catalogued as COSV54588886; called by muse, mutect2
- RBMS2 | c.243G>T p.K81N | Missense Mutation (SNP) | VAF 252/656 reads (38%) | SIFT tolerated (0.18); PolyPhen benign (0.145); catalogued as COSV100008746; called by muse, mutect2, varscan2
- RECQL4 | c.371G>A p.G124D | Missense Mutation (SNP) | VAF 139/348 reads (40%) | SIFT tolerated (0.5); PolyPhen benign (0.315); catalogued as rs368160871; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- RET | c.1357G>T p.G453W | Missense Mutation (SNP) | VAF 63/599 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.955); catalogued as COSV60713724; called by muse, mutect2, varscan2
- RETSAT | c.1720G>A p.V574I | Missense Mutation (SNP) | VAF 50/1452 reads (3%) | SIFT tolerated (0.53); PolyPhen benign (0.027); catalogued as rs1198176836, COSV99806351; called by muse, mutect2
- REXO4 | c.265C>A p.L89I | Missense Mutation (SNP) | VAF 199/599 reads (33%) | SIFT tolerated (0.29); PolyPhen benign (0.014); catalogued as COSV104426293; called by muse, mutect2, varscan2
5,496 further variants in this file (3,190 protein-altering or splice-affecting, 1,053 silent, 1,253 other) are not listed here.
